Somatic mutation profile of tumor specimen TCGA-EB-A5UM-01A (aliquot TCGA-EB-A5UM-01A-11D-A30X-08) from TCGA case TCGA-EB-A5UM, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIC; Age at diagnosis: 48.9 years (17,867 days).
Specimen TCGA-EB-A5UM-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 976edfca-fef9-420e-b3d2-5689dc0112a4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EB-A5UM-10A (Blood Derived Normal), aliquot TCGA-EB-A5UM-10A-01D-A30X-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c909d683-6aa0-4f09-afcd-6a8317fa4472

The open-access MAF lists 672 somatic variants for this specimen: 447 protein-altering or splice-affecting, 212 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 414, Silent 212, Nonsense Mutation 20, RNA 6, Intron 5, Frame Shift Del 4, Splice Region 4, Splice Site 3, 3'UTR 1, Translation Start Site 1, 5'Flank 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 39/81 reads (48%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen benign (0.083); catalogued as rs121913238, COSV55502066, COSV55502677; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MYO9A | c.3898C>T p.P1300S | Missense Mutation (SNP) | VAF 33/79 reads (42%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.964); catalogued as COSV61847987; called by muse, mutect2, varscan2
- PSG4 | c.787G>A p.E263K | Missense Mutation (SNP) | VAF 83/247 reads (34%) | hotspot (GDC flag); SIFT tolerated (0.29); PolyPhen possibly damaging (0.854); catalogued as COSV54932991; called by muse, mutect2, varscan2
- SLC27A5 | c.1661C>T p.T554I | Missense Mutation (SNP) | VAF 6/46 reads (13%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs202081924, COSV54017957; called by muse, mutect2, varscan2
- AARS1 | c.599C>T p.A200V | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.776); catalogued as rs776896056, COSV55750109; called by muse, mutect2, varscan2
- ABAT | c.1307G>A p.R436Q | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT tolerated (0.33); PolyPhen benign (0.059); catalogued as rs764665721, COSV51629662; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ABCA10 | c.2594C>T p.S865F | Missense Mutation (SNP) | VAF 67/180 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.445); catalogued as COSV52231126; called by muse, mutect2, varscan2
- ABCD2 | c.1519C>T p.L507F | Missense Mutation (SNP) | VAF 9/102 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.349); catalogued as COSV58055815; called by muse, mutect2
- ABHD12 | c.260C>T p.P87L | Missense Mutation (SNP) | VAF 23/42 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59289733; called by muse, mutect2, varscan2
- AC126283.2 | c.959C>T p.S320L | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.536); catalogued as COSV67099940; called by muse, mutect2, varscan2
- ACAN | c.1734G>A p.G578= | Splice Region (SNP) | VAF 4/18 reads (22%) | catalogued as COSV61371451; called by mutect2, varscan2
- ADAM7 | c.580G>A p.G194S | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT tolerated (0.98); PolyPhen benign (0); catalogued as COSV51548090; called by muse, mutect2, varscan2
- ADAM8 | c.2290C>T p.P764S | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs532126257, COSV69865417; called by muse, mutect2
- ADAMTS19 | c.1949C>T p.P650L | Missense Mutation (SNP) | VAF 40/152 reads (26%) | SIFT tolerated (0.26); PolyPhen benign (0.096); catalogued as COSV50752865; called by muse, mutect2, varscan2
- ADAMTSL3 | c.278G>A p.G93E | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54474199, COSV99716650; called by muse, mutect2, varscan2
- ADCY4 | c.2965C>T p.H989Y | Missense Mutation (SNP) | VAF 38/124 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.248); catalogued as COSV60258374; called by muse, mutect2, varscan2
- ADD2 | c.717G>A p.M239I | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.667); catalogued as rs782070720, COSV52473889; called by muse, mutect2, varscan2
- ADGRF1 | c.1952T>G p.V651G | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as COSV51948445; called by muse, mutect2, varscan2
- ADGRF3 | c.3116A>C p.Q1039P (on ENST00000311519 / NM_001145168.1; = p.Q840P on NM_153835.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/95 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.356); catalogued as COSV61054015; called by muse, mutect2, varscan2
- AHNAK | c.17159C>T p.S5720F | Missense Mutation (SNP) | VAF 43/130 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57205006; called by muse, mutect2, varscan2
- AHNAK2 | c.13802C>T p.P4601L | Missense Mutation (SNP) | VAF 16/113 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.08); catalogued as COSV60934102; called by muse, mutect2, varscan2
- AHNAK2 | c.11453del p.P3818Qfs*20 | Frame Shift Del (DEL) | VAF 66/280 reads (24%) | catalogued as COSV60934270; called by pindel, varscan2
- AKAP13 | c.7822C>T p.R2608C (on ENST00000394518 / NM_007200.5; = p.R2612C on NM_006738.6) | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.052); catalogued as rs750119172, COSV63472181; called by muse, mutect2, varscan2
- AKAP13 | c.8186C>T p.P2729L (on ENST00000394518 / NM_007200.5; = p.P2733L on NM_006738.6) | Missense Mutation (SNP) | VAF 73/207 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1433451919, COSV63472188; called by muse, mutect2, varscan2
- AKAP9 | c.9050C>T p.S3017F (on ENST00000359028; = p.S2993F on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62355899; called by muse, mutect2, varscan2
- ALB | c.647C>T p.S216L | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT tolerated (0.38); PolyPhen benign (0.037); catalogued as rs1485868409, COSV55737756; called by muse, mutect2, varscan2
- ALOX15B | c.1426G>A p.D476N | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1404290663, COSV66480326; called by muse, mutect2, varscan2
- ALS2 | c.8C>T p.S3L | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.014); catalogued as COSV51894109; called by muse, mutect2, varscan2
- ANO2 | c.790G>A p.E264K (on ENST00000356134 / NM_001278597.3; = p.E268K on NM_001278596.3) | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as COSV59047961; called by muse, mutect2, varscan2
- AP4E1 | c.3077C>T p.S1026L | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as COSV55921033, COSV99957262; called by muse, mutect2, varscan2
- APBB1IP | c.502G>A p.E168K | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.876); catalogued as COSV63301661; called by muse, mutect2, varscan2
- APOB | c.6457G>A p.E2153K | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT tolerated (0.71); PolyPhen benign (0.371); catalogued as rs767731326, COSV51926138; called by muse, mutect2
- APOBEC3F | c.211C>T p.L71F | Missense Mutation (SNP) | VAF 74/133 reads (56%) | SIFT tolerated (0.05); PolyPhen benign (0.046); catalogued as COSV57912155; called by muse, mutect2, varscan2
- ARHGAP36 | c.865G>A p.D289N | Missense Mutation (SNP) | VAF 39/125 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as COSV52268178, COSV52272069; called by muse, mutect2, varscan2
- ARHGAP36 | c.1323G>A p.W441* | Nonsense Mutation (SNP) | VAF 30/81 reads (37%) | catalogued as COSV52273625; called by muse, mutect2, varscan2
- ARHGAP45 | c.3091G>A p.D1031N | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV53125610; called by muse, mutect2, varscan2
- ARHGEF10 | c.1338A>C p.Q446H (on ENST00000398564; = p.Q421H on NM_014629.4) | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT tolerated (0.12); PolyPhen benign (0.113); catalogued as COSV50688510; called by muse, mutect2, varscan2
- ARSF | c.1411C>T p.H471Y | Missense Mutation (SNP) | VAF 24/88 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.807); catalogued as COSV63841361; called by muse, mutect2, varscan2
- ART5 | c.278G>A p.G93E | Missense Mutation (SNP) | VAF 41/111 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as COSV51707826; called by muse, mutect2, varscan2
- ASAH1 | c.523A>G p.R175G | Missense Mutation (SNP) | VAF 119/336 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV50505424; called by muse, mutect2, varscan2
- ASB15 | c.134G>A p.R45K | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs144930255, COSV51923517, COSV51929992; called by muse, mutect2, varscan2
- ASCL3 | c.302G>A p.R101Q | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs188564430; called by muse, mutect2, varscan2
- ASTN1 | c.1580C>T p.P527L | Missense Mutation (SNP) | VAF 32/84 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.272); catalogued as rs766514135, COSV56090595; called by muse, mutect2, varscan2
- ASTN1 | c.613C>T p.P205S | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs145957941, COSV56082361; called by muse, varscan2
- B4GALT4 | c.650T>C p.V217A | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.955); catalogued as rs1216080152, COSV63296571; called by muse, mutect2, varscan2
- BCO1 | c.1616C>T p.S539F | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.033); catalogued as COSV50729041; called by muse, mutect2, varscan2
- BMP3 | c.845C>T p.S282F | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.275); catalogued as COSV51082904; called by muse, mutect2, varscan2
- BMP6 | c.1454C>T p.A485V | Missense Mutation (SNP) | VAF 80/281 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV51673783; called by muse, mutect2, varscan2
- BPTF | c.5603A>T p.Y1868F | Missense Mutation (SNP) | VAF 17/160 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.142); catalogued as COSV58849392; called by muse, mutect2
- BPTF | c.5605T>C p.F1869L | Missense Mutation (SNP) | VAF 18/161 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV58849405; called by muse, mutect2
- C12orf40 | c.1289G>A p.G430E | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT tolerated (0.26); PolyPhen benign (0.22); catalogued as rs267603453, COSV61137277; called by muse, mutect2, varscan2
- C16orf89 | c.782G>A p.G261D | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.397); catalogued as rs770082606, COSV60122366; called by muse, mutect2
- C1orf127 | c.949C>T p.P317S | Missense Mutation (SNP) | VAF 26/50 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV65439392; called by muse, mutect2, varscan2
- C22orf42 | c.272G>A p.W91* | Nonsense Mutation (SNP) | VAF 31/91 reads (34%) | catalogued as COSV66076803; called by muse, mutect2, varscan2
- C2orf16 | c.371G>A p.R124K | Missense Mutation (SNP) | VAF 29/82 reads (35%) | SIFT tolerated (0.22); PolyPhen benign (0.013); catalogued as COSV68647510; called by muse, mutect2, varscan2
- C3orf20 | c.900G>A p.W300* | Nonsense Mutation (SNP) | VAF 19/59 reads (32%) | catalogued as COSV53790450; called by muse, mutect2, varscan2
- C6 | c.2519G>A p.G840D | Missense Mutation (SNP) | VAF 55/157 reads (35%) | SIFT tolerated (0.68); PolyPhen benign (0.007); catalogued as COSV54721246; called by muse, mutect2, varscan2
- CACNA1B | c.3386C>T p.S1129F | Missense Mutation (SNP) | VAF 81/254 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV53153463; called by muse, mutect2, varscan2
- CACNA1G | c.3632C>T p.A1211V | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs916556702, COSV61720642; called by muse, mutect2, varscan2
- CATSPER1 | c.1801C>T p.L601F | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.979); catalogued as rs1431593593, COSV56414177; called by muse, mutect2, varscan2
- CCDC178 | c.2590G>A p.E864K (on ENST00000383096 / NM_001105528.3; = p.E826K on NM_198995.3) | Missense Mutation (SNP) | VAF 24/51 reads (47%) | SIFT tolerated (0.18); PolyPhen benign (0.033); catalogued as rs370055815; called by muse, mutect2, varscan2
- CCDC38 | c.496C>T p.R166* | Nonsense Mutation (SNP) | VAF 63/96 reads (66%) | catalogued as rs562119371, COSV60185438; called by muse, mutect2, varscan2
- CCDC85A | c.1607C>T p.S536L | Missense Mutation (SNP) | VAF 30/72 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); catalogued as rs765502186, COSV101339350, COSV68149842; called by muse, mutect2, varscan2
- CCDC88C | c.4156G>A p.E1386K | Missense Mutation (SNP) | VAF 7/10 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV66242726; called by muse, mutect2, varscan2
- CD163 | c.3338C>T p.S1113F | Missense Mutation (SNP) | VAF 36/123 reads (29%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.564); catalogued as COSV63129495; called by muse, mutect2, varscan2
- CD244 | c.340G>A p.G114R | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59242408; called by muse, mutect2, varscan2
- CDC14A | c.1649C>T p.P550L | Missense Mutation (SNP) | VAF 22/40 reads (55%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); catalogued as COSV60564857; called by muse, mutect2, varscan2
- CDCA2 | c.1292C>T p.S431F | Missense Mutation (SNP) | VAF 37/106 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.308); catalogued as COSV57949194; called by muse, mutect2, varscan2
- CDH1 | c.1381C>T p.P461S | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.254); catalogued as COSV55743017; called by muse, mutect2, varscan2
- CDH9 | c.1123G>A p.E375K | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT tolerated (0.23); PolyPhen benign (0.398); catalogued as COSV50483092; called by muse, mutect2, varscan2
- CFAP100 | c.226G>A p.E76K | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.283); catalogued as COSV61505002; called by muse, mutect2, varscan2
- CFAP298-TCP10L | c.1142C>T p.P381L | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV55829833; called by muse, mutect2, varscan2
- CH25H | c.718G>A p.D240N | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV64092619; called by muse, mutect2, varscan2
- CHGB | c.718G>A p.G240R | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT tolerated (0.66); PolyPhen benign (0.037); catalogued as COSV66762123; called by muse, mutect2, varscan2
- CLCC1 | c.1489G>A p.V497I (on ENST00000356970 / NM_001377464.1; = p.V447I on NM_015127.5) | Missense Mutation (SNP) | VAF 57/88 reads (65%) | SIFT tolerated (0.22); PolyPhen benign (0.131); catalogued as COSV51445034; called by muse, mutect2, varscan2
- CLCNKB | c.1601G>A p.R534Q | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated (0.24); PolyPhen benign (0.298); catalogued as rs775877075, COSV100990262, COSV65162119; called by muse, mutect2, varscan2
- CLIP1 | c.328C>T p.Q110* | Nonsense Mutation (SNP) | VAF 67/105 reads (64%) | catalogued as COSV56810096; called by muse, mutect2, varscan2
- CLN3 | c.473C>T p.S158F (on ENST00000360019 / NM_001286104.2; = p.S182F on NM_000086.2) | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.816); catalogued as COSV61108170; called by muse, mutect2, varscan2
- COIL | c.740C>T p.S247F | Missense Mutation (SNP) | VAF 37/113 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.785); catalogued as COSV53597037; called by muse, mutect2, varscan2
- COL18A1 | c.269G>A p.G90D | Missense Mutation (SNP) | VAF 29/132 reads (22%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.009); catalogued as COSV62708363; called by muse, mutect2, varscan2
- COL1A1 | c.659G>A p.R220Q | Missense Mutation (SNP) | VAF 33/106 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs200142836, COSV56810523; called by muse, mutect2, varscan2
- COL20A1 | c.202G>A p.E68K | Missense Mutation (SNP) | VAF 14/16 reads (88%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); catalogued as COSV58921385; called by muse, mutect2
- COL9A1 | c.1591C>T p.P531S | Missense Mutation (SNP) | VAF 105/217 reads (48%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV57879770; called by muse, mutect2, varscan2
- COLEC10 | c.302G>T p.G101V | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60523251; called by muse, mutect2, varscan2
- CPLX2 | c.271G>A p.E91K | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as rs772923966, COSV64002560; called by muse, mutect2, varscan2
- CR1 | c.2295C>A p.N765K | Missense Mutation (SNP) | VAF 39/117 reads (33%) | SIFT tolerated (0.95); PolyPhen benign (0); catalogued as COSV65464997; called by muse, mutect2, varscan2
- CRYBA1 | c.394G>A p.E132K | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.851); catalogued as COSV56601713; called by muse, mutect2, varscan2
- CSF3R | c.877G>A p.E293K | Missense Mutation (SNP) | VAF 24/41 reads (59%) | SIFT tolerated (0.21); PolyPhen benign (0.018); catalogued as COSV58973366; called by muse, mutect2, varscan2
- CSMD1 | c.3563C>T p.S1188F (on ENST00000520002; = p.S1187F on NM_033225.6) | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV100144590, COSV59399107; called by muse, mutect2, varscan2
- CUL9 | c.7051G>A p.V2351M | Missense Mutation (SNP) | VAF 17/135 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1458331166, COSV52736350; called by muse, mutect2, varscan2
- CXXC1 | c.307C>T p.R103W | Missense Mutation (SNP) | VAF 71/194 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.825); catalogued as rs141867524; called by muse, mutect2, varscan2
- CYLC1 | c.554C>T p.S185F | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated (0.73); PolyPhen benign (0.043); catalogued as rs867114390, COSV61416778; called by muse, mutect2, varscan2
- CYLD | c.1564C>T p.R522W | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs1261903918, COSV61094701; called by muse, mutect2, varscan2
- CYP2A6 | c.857T>A p.F286Y | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.765); catalogued as COSV56537693; called by muse, mutect2, varscan2
- CYP4A22 | c.1478G>A p.R493Q | Missense Mutation (SNP) | VAF 33/50 reads (66%) | SIFT tolerated (1); PolyPhen benign (0.086); catalogued as rs767886913, COSV53738388; called by muse, mutect2, varscan2
- CYP7B1 | c.218T>G p.L73R | Missense Mutation (SNP) | VAF 36/113 reads (32%) | SIFT tolerated (0.21); PolyPhen benign (0.147); catalogued as COSV59598819; called by muse, mutect2, varscan2
- DDHD1 | c.1387C>T p.P463S (on ENST00000323669; = p.P660S on NM_030637.3) | Missense Mutation (SNP) | VAF 12/118 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60363502; called by muse, mutect2, varscan2
- DENND5B | c.1666C>T p.P556S | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as rs1416680550, COSV60909833; called by muse, mutect2, varscan2
- DES | c.967G>A p.E323K | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as COSV64660235; called by muse, mutect2, varscan2
- DGKD | c.520C>T p.P174S (on ENST00000264057 / NM_152879.3; = p.P130S on NM_003648.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 61/139 reads (44%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.525); catalogued as COSV51060605; called by muse, mutect2, varscan2
- DGKD | c.2102C>T p.S701F (on ENST00000264057 / NM_152879.3; = p.S657F on NM_003648.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 72/178 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.19); catalogued as COSV51121671; called by muse, mutect2, varscan2
- DMWD | c.1214C>T p.P405L | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.999); catalogued as COSV52183553; called by muse, mutect2, varscan2
- DNAH11 | c.10536G>A p.M3512I | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as rs759819257, COSV60960070; called by mutect2, varscan2
- DNAH17 | c.9142G>A p.G3048S | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs969488312, COSV67762670; called by muse, mutect2, varscan2
- DNAH3 | c.6652G>A p.D2218N | Missense Mutation (SNP) | VAF 28/80 reads (35%) | SIFT tolerated (0.2); PolyPhen benign (0.026); catalogued as COSV54559437; called by muse, mutect2, varscan2
- DNAH7 | c.8518G>A p.E2840K | Missense Mutation (SNP) | VAF 65/236 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0.021); catalogued as COSV56753749; called by muse, mutect2, varscan2
- DNAH7 | c.2407T>C p.Y803H | Missense Mutation (SNP) | VAF 47/149 reads (32%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.814); catalogued as COSV56791509; called by muse, mutect2, varscan2
- DNAH9 | c.10639C>T p.P3547S | Missense Mutation (SNP) | VAF 33/85 reads (39%) | SIFT tolerated (0.18); PolyPhen benign (0.129); catalogued as rs776858112, COSV52382591; called by muse, mutect2, varscan2
- DOCK11 | c.6035A>T p.Y2012F | Missense Mutation (SNP) | VAF 32/129 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52249559; called by muse, mutect2, varscan2
- DPRX | c.22C>T p.R8C | Missense Mutation (SNP) | VAF 49/122 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.046); catalogued as rs148896232; called by muse, mutect2, varscan2
- DRD2 | c.646C>T p.L216F | Missense Mutation (SNP) | VAF 31/91 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60763732; called by muse, mutect2, varscan2
- DUS3L | c.619C>T p.R207C | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.006); catalogued as rs942541725, COSV57834025; called by muse, mutect2, varscan2
- DUSP29 | c.217C>T p.R73C | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.135); catalogued as rs776538597, COSV58300187, COSV58300610; called by muse, mutect2, varscan2
- ECH1 | c.350-1G>A p.X117_splice | Splice Site (SNP) | VAF 8/18 reads (44%) | catalogued as COSV55490582; called by muse, mutect2, varscan2
- EEFSEC | c.775C>T p.P259S | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.941); catalogued as rs755656837, COSV54634603; called by muse, mutect2, varscan2
- EGFLAM | c.1406G>A p.G469E | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1406516911; called by muse, mutect2
- EGR2 | c.1067A>G p.E356G | Missense Mutation (SNP) | VAF 36/94 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as COSV54349280; called by muse, mutect2, varscan2
- EIF4G2 | c.1204C>T p.R402C | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as COSV60599519; called by muse, mutect2, varscan2
- ELK1 | c.583G>A p.G195R | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV55955057; called by muse, mutect2, varscan2
- ENPEP | c.1025C>T p.S342F | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.83); catalogued as COSV54458975, COSV99487303; called by muse, varscan2
- ENPP6 | c.1268C>T p.P423L | Missense Mutation (SNP) | VAF 50/120 reads (42%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs1299285167, COSV57073479; called by muse, mutect2
- EPHA10 | c.2446G>A p.E816K | Missense Mutation (SNP) | VAF 25/51 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs192256218, COSV57624285, COSV57624396; called by muse, mutect2, varscan2
- ERBB4 | c.1549C>G p.P517A | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV53535367, COSV53581816; called by muse, mutect2, varscan2
- ERC2 | c.1580T>A p.I527N | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV55672807; called by muse, mutect2, varscan2
- ESM1 | c.217G>A p.D73N | Missense Mutation (SNP) | VAF 31/64 reads (48%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.862); catalogued as rs1314334788, COSV67319053; called by muse, mutect2, varscan2
- ESPN | c.2213C>T p.A738V | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT deleterious (0.02); PolyPhen benign (0.185); catalogued as rs760438308, COSV64705453, COSV64705635; called by muse, mutect2, varscan2
- ETAA1 | c.584C>T p.A195V | Missense Mutation (SNP) | VAF 15/29 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55475662; called by muse, mutect2, varscan2
- ETFA | c.118A>G p.T40A | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT tolerated (0.84); PolyPhen benign (0.003); catalogued as COSV51212608; called by muse, mutect2, varscan2
- ETNPPL | c.853C>T p.P285S | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV56598128; called by muse, mutect2, varscan2
- EXOSC4 | c.547C>T p.P183S | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.432); catalogued as rs1003494401, COSV100284118; called by muse, mutect2, varscan2
- FAM120B | c.1876C>T p.R626* | Nonsense Mutation (SNP) | VAF 27/45 reads (60%) | catalogued as rs746753927, COSV53009303; called by muse, mutect2, varscan2
- FAM133A | c.286A>C p.K96Q | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.037); catalogued as COSV59078192; called by muse, mutect2
- FAM171A1 | c.2459C>T p.S820L | Missense Mutation (SNP) | VAF 27/62 reads (44%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs1369563832, COSV65321039; called by muse, mutect2, varscan2
- FAM47C | c.1156C>T p.R386C | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV63731112; called by muse, mutect2, varscan2
- FAM90A1 | c.601G>A p.E201K | Missense Mutation (SNP) | VAF 37/144 reads (26%) | SIFT tolerated (0.44); PolyPhen benign (0.015); catalogued as rs968751949, COSV56710002; called by muse, mutect2, varscan2
- FAM90A1 | c.223G>A p.E75K | Missense Mutation (SNP) | VAF 67/132 reads (51%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56712233, COSV56712922; called by muse, mutect2, varscan2
- FANCG | c.1769C>T p.P590L | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV62722473; called by muse, mutect2, varscan2
- FBP2 | c.455A>T p.D152V | Missense Mutation (SNP) | VAF 21/36 reads (58%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV64696068; called by muse, mutect2, varscan2
- FFAR4 | c.808C>T p.R270C | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); catalogued as rs775130919, COSV65160907; called by muse, mutect2, varscan2
- FGFR4 | c.2041G>A p.E681K | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52801409; called by muse, mutect2, varscan2
- FNDC3B | c.725C>T p.P242L | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.206); catalogued as COSV61051526; called by mutect2, varscan2
- FNIP1 | c.794T>C p.L265S | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.493); catalogued as COSV100330501; called by muse, mutect2, varscan2
- FRMD5 | c.467G>A p.G156D | Missense Mutation (SNP) | VAF 28/56 reads (50%) | SIFT tolerated (0.36); PolyPhen probably damaging (1); catalogued as rs772266766, COSV68726241; called by muse, mutect2, varscan2
- FRY | c.8289C>T p.L2763= | Splice Region (SNP) | VAF 21/66 reads (32%) | catalogued as COSV66582282; called by muse, mutect2, varscan2
- FYCO1 | c.3451C>T p.L1151F | Missense Mutation (SNP) | VAF 25/44 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs375082007; called by muse, mutect2, varscan2
- GABRG2 | c.1261G>A p.D421N (on ENST00000361925 / NM_001375343.1; = p.D381N on NM_000816.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/78 reads (36%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.997); catalogued as COSV62723531; called by muse, mutect2, varscan2
- GABRQ | c.1399C>T p.R467C | Missense Mutation (SNP) | VAF 60/173 reads (35%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.401); catalogued as rs138966264, COSV64780848; called by muse, mutect2, varscan2
- GCC2 | c.2249T>C p.V750A | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as COSV59180678; called by muse, mutect2, varscan2
- GCM1 | c.554G>A p.G185E | Missense Mutation (SNP) | VAF 16/134 reads (12%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as COSV52524470, COSV99452026; called by muse, mutect2
- GHRHR | c.745G>A p.G249S | Missense Mutation (SNP) | VAF 27/64 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV58198468; called by muse, mutect2, varscan2
- GIMAP2 | c.206G>A p.G69E | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0.127); catalogued as COSV56236625; called by muse, mutect2, varscan2
- GLRA3 | c.821C>T p.S274L | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs771115012, COSV56857256; called by muse, mutect2, varscan2
- GLT6D1 | c.199G>A p.E67K | Missense Mutation (SNP) | VAF 34/83 reads (41%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.715); catalogued as COSV65627769; called by muse, varscan2
- GNAS | c.1684C>T p.R562C | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); catalogued as rs1278876119, COSV58336884; called by muse, mutect2, varscan2
- GNB2 | c.956G>A p.G319E | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99309642; called by muse, mutect2, varscan2
- GPAM | c.1621G>A p.G541R | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.946); catalogued as COSV62082981; called by muse, mutect2
- GPATCH8 | c.3941C>T p.P1314L | Missense Mutation (SNP) | VAF 38/105 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV59192977, COSV59199804; called by muse, mutect2, varscan2
- GPR26 | c.604C>T p.H202Y | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52935818, COSV52937434; called by muse, mutect2
- GPR45 | c.562G>A p.E188K | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.534); catalogued as COSV51525623; called by muse, mutect2, varscan2
- GREB1 | c.631G>A p.G211S | Missense Mutation (SNP) | VAF 33/95 reads (35%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.984); catalogued as rs1218630074, COSV52198507; called by muse, mutect2, varscan2
- GRID2 | c.491C>T p.A164V | Missense Mutation (SNP) | VAF 20/91 reads (22%) | SIFT tolerated (0.37); PolyPhen benign (0.098); catalogued as COSV99942827; called by muse, mutect2, varscan2
- GRIK1 | c.1430G>A p.G477E | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58724926; called by muse, mutect2
- GRIN2A | c.3523G>A p.E1175K | Missense Mutation (SNP) | VAF 91/283 reads (32%) | SIFT tolerated (0.52); PolyPhen benign (0.185); catalogued as rs867464241, COSV58027342, COSV58033157; called by muse, mutect2, varscan2
- GUCA1C | c.115G>A p.E39K | Missense Mutation (SNP) | VAF 32/112 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.204); catalogued as rs1265768088, COSV51712957; called by muse, mutect2, varscan2
- GUCY2C | c.3134A>G p.Q1045R | Missense Mutation (SNP) | VAF 143/288 reads (50%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs35617837, COSV53789876, COSV53796996; called by muse, mutect2, varscan2
- HELLS | c.1702C>T p.R568C | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1284553236, COSV53302045; called by muse, mutect2, varscan2
- HIVEP1 | c.500C>T p.S167F | Missense Mutation (SNP) | VAF 37/260 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV65104238; called by muse, mutect2, varscan2
- HPS4 | c.1451C>T p.P484L | Missense Mutation (SNP) | VAF 75/311 reads (24%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as COSV61106449; called by muse, mutect2, varscan2
- HSF1 | c.319G>A p.G107S | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101275168; called by muse, mutect2, varscan2
- HSF1 | c.320G>A p.G107D | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68821692; called by muse, mutect2, varscan2
- HYDIN | c.4351C>T p.Q1451* | Nonsense Mutation (SNP) | VAF 25/110 reads (23%) | catalogued as COSV66832417; called by muse, mutect2, varscan2
- IGDCC3 | c.829C>T p.R277C | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.392); catalogued as rs748517642, COSV60080986; called by muse, mutect2, varscan2
- IQCH | c.1367C>T p.S456L | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60061609; called by muse, mutect2, varscan2
- IRS4 | c.1174G>A p.E392K | Missense Mutation (SNP) | VAF 27/123 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as rs143812272, COSV64535021; called by muse, mutect2, varscan2
- ISLR | c.946G>A p.D316N | Missense Mutation (SNP) | VAF 23/48 reads (48%) | SIFT tolerated (0.53); PolyPhen benign (0.01); catalogued as rs374131148; called by muse, mutect2, varscan2
- ITGAD | c.2927G>A p.G976E | Missense Mutation (SNP) | VAF 24/93 reads (26%) | SIFT tolerated (0.47); PolyPhen benign (0.085); catalogued as COSV54932929; called by muse, mutect2, varscan2
- ITIH2 | c.959C>T p.S320F | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773878560, COSV64435659; called by muse, mutect2, varscan2
- ITIH4 | c.718C>T p.R240C | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs746358787, COSV56572741; called by muse, mutect2, varscan2
- ITPR1 | c.5665G>A p.D1889N (on ENST00000354582; = p.D1834N on NM_002222.7) | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.247); catalogued as rs370615766, COSV56982714; called by muse, mutect2, varscan2
- IWS1 | c.2050G>T p.E684* | Nonsense Mutation (SNP) | VAF 50/140 reads (36%) | catalogued as COSV54872496; called by muse, mutect2, varscan2
- KANK4 | c.2059C>T p.P687S | Missense Mutation (SNP) | VAF 27/42 reads (64%) | SIFT tolerated (1); PolyPhen benign (0.018); catalogued as rs1557484374, COSV100587601, COSV62989882; called by muse, mutect2, varscan2
- KAT6B | c.1352C>T p.S451L | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.018); catalogued as COSV54756426; called by muse, mutect2, varscan2
- KATNAL2 | c.644C>T p.P215L (on ENST00000356157 / NM_001353899.1; = p.P143L on NM_031303.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.076); catalogued as COSV55310614; called by muse, mutect2, varscan2
- KATNIP | c.3827A>G p.N1276S | Missense Mutation (SNP) | VAF 26/81 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV55194293; called by muse, mutect2, varscan2
- KCNB1 | c.1350G>A p.M450I | Missense Mutation (SNP) | VAF 43/269 reads (16%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs764707658, COSV65566040, COSV65571505; called by muse, mutect2, varscan2
- KCNG4 | c.656C>T p.P219L | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.703); catalogued as rs774022999, COSV57586621; called by muse, mutect2, varscan2
- KCNH7 | c.914G>A p.G305E | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1323610941, COSV59817854; called by muse, mutect2, varscan2
- KCNV2 | c.533C>T p.P178L | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs144949136, CM074299; called by muse, mutect2, varscan2
- KIAA1210 | c.485A>T p.K162M | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68180889; called by muse, mutect2, varscan2
- KIF13B | c.2494C>T p.R832W | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101568718, COSV72879484; called by muse, mutect2, varscan2
- KIF21B | c.1786G>A p.E596K | Missense Mutation (SNP) | VAF 15/87 reads (17%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.959); catalogued as rs892966441, COSV59753268; called by muse, mutect2, varscan2
- KLHL7 | c.835G>A p.E279K (on ENST00000339077 / NM_001031710.3; = p.E231K on NM_018846.5) | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.78); PolyPhen benign (0.003); catalogued as COSV59160087; called by muse, varscan2
- KRTAP13-1 | c.413C>T p.P138L | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV62664629; called by muse, mutect2, varscan2
- KRTAP21-2 | c.155G>A p.G52E | Missense Mutation (SNP) | VAF 30/75 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.977); catalogued as COSV61684771; called by muse, mutect2, varscan2
- KRTAP24-1 | c.290C>T p.S97F | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.169); catalogued as COSV100447359, COSV61089737; called by muse, mutect2, varscan2
- KYNU | c.539G>A p.G180E | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV51593594; called by muse, mutect2, varscan2
- LAMA3 | c.2348C>T p.S783F | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT tolerated (0.59); PolyPhen possibly damaging (0.635); catalogued as COSV58083821; called by muse, mutect2, varscan2
- LAMA3 | c.5009C>T p.P1670L (on ENST00000313654 / NM_198129.4; = p.P61L on NM_000227.6) | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.945); catalogued as COSV52545382, COSV99334576; called by muse, mutect2, varscan2
- LAMA5 | c.2737C>T p.Q913* | Nonsense Mutation (SNP) | VAF 17/63 reads (27%) | catalogued as COSV99440955; called by muse, mutect2, varscan2
- LAMC2 | c.514G>A p.G172S | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); catalogued as COSV51455211, COSV51460598; called by muse, mutect2, varscan2
- LCE3A | c.86C>T p.S29F | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.073); catalogued as COSV59550826; called by muse, mutect2, varscan2
- LCE5A | c.230C>T p.S77F | Missense Mutation (SNP) | VAF 27/100 reads (27%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.015); catalogued as COSV57501797; called by muse, mutect2, varscan2
- LDB2 | c.788C>T p.S263F | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58767584; called by muse, mutect2, varscan2
- LHCGR | c.1661G>A p.R554Q | Missense Mutation (SNP) | VAF 24/83 reads (29%) | SIFT tolerated (0.37); PolyPhen benign (0.005); catalogued as rs754675508, COSV54302413; called by muse, mutect2, varscan2
- LHX3 | c.203G>A p.R68H (on ENST00000371748 / NM_178138.6; = p.R73H on NM_014564.5) | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as rs377183234; called by muse, mutect2, varscan2
- LILRB1 | c.946G>A p.A316T (on ENST00000427581; = p.A280T on NM_006669.6) | Missense Mutation (SNP) | VAF 40/106 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.189); catalogued as rs1366669678, COSV61122433; called by muse, mutect2
- LILRB4 | c.293G>A p.C98Y | Missense Mutation (SNP) | VAF 71/187 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54409381; called by muse, mutect2, varscan2
- LINS1 | c.1960C>T p.Q654* | Nonsense Mutation (SNP) | VAF 24/76 reads (32%) | catalogued as rs1178251339, COSV59081267; called by muse, mutect2
- LIPE | c.266C>T p.A89V | Missense Mutation (SNP) | VAF 79/237 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.006); catalogued as rs138280510; called by muse, mutect2, varscan2
- LMF2 | c.1903G>C p.A635P | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.48); PolyPhen benign (0.001); catalogued as COSV53319633; called by muse, mutect2, varscan2
- LMO7 | c.2152G>A p.E718K (on ENST00000357063; = p.E399K on NM_005358.5) | Missense Mutation (SNP) | VAF 34/103 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV58552011; called by muse, mutect2, varscan2
- LMTK3 | c.1024G>A p.E342K | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV54318301; called by muse, mutect2, varscan2
- LPGAT1 | c.62G>A p.R21K | Missense Mutation (SNP) | VAF 59/168 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV65352766; called by muse, mutect2, varscan2
- LRGUK | c.440G>A p.G147E | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.42); PolyPhen benign (0.006); catalogued as COSV53645130; called by muse, mutect2, varscan2
- LRRC23 | c.559C>T p.R187W | Missense Mutation (SNP) | VAF 58/115 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs782748706, COSV50386825; called by muse, mutect2, varscan2
- LYRM4 | c.157C>T p.Q53* | Nonsense Mutation (SNP) | VAF 18/101 reads (18%) | catalogued as COSV57995904; called by muse, mutect2, varscan2
- LYST | c.6446C>G p.S2149C | Missense Mutation (SNP) | VAF 33/95 reads (35%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.106); catalogued as COSV101088315, COSV67715850; called by muse, mutect2, varscan2
- MACROH2A2 | c.1093G>A p.E365K | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV57161148; called by muse, mutect2, varscan2
- MAN2A2 | c.2479C>T p.P827S | Missense Mutation (SNP) | VAF 26/96 reads (27%) | SIFT tolerated (0.46); PolyPhen benign (0.017); catalogued as rs762951236, COSV100847921; called by muse, mutect2, varscan2
- MAP3K19 | c.2750C>T p.S917F | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT tolerated (0.11); PolyPhen benign (0.023); catalogued as COSV59642998; called by muse, mutect2, varscan2
- MAP3K21 | c.1417G>A p.D473N | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.133); catalogued as rs774035001, COSV64047242; called by muse, mutect2, varscan2
- MAP4K4 | c.3464T>C p.V1155A (on ENST00000347699 / NM_001242559.2; = p.V1081A on NM_004834.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 52/136 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.472); catalogued as COSV56342931; called by muse, mutect2, varscan2
- MAP7D3 | c.472G>A p.D158N | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.907); catalogued as rs376263354, COSV60173082; called by muse, mutect2, varscan2
- MAP9 | c.992C>T p.P331L | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.564); catalogued as COSV60906964; called by muse, mutect2, varscan2
- MAPK13 | c.955G>A p.E319K | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT tolerated (0.51); PolyPhen benign (0.006); catalogued as COSV52985565; called by muse, mutect2, varscan2
- MBD5 | c.3652C>T p.H1218Y | Missense Mutation (SNP) | VAF 33/110 reads (30%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.001); catalogued as rs753060251, COSV68698473; ClinVar: likely benign; called by muse, mutect2, varscan2
- MDC1 | c.581C>T p.P194L | Missense Mutation (SNP) | VAF 29/50 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.748); catalogued as COSV64528546; called by muse, mutect2, varscan2
- MEFV | c.661C>T p.P221S | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT tolerated (0.92); PolyPhen benign (0.353); catalogued as rs528185784, COSV54828867; called by muse, mutect2, varscan2
- MEP1A | c.2048G>A p.G683D | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57923029; called by muse, mutect2, varscan2
- MEPE | c.1386A>G p.I462M | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT tolerated (0.2); PolyPhen benign (0.171); catalogued as COSV63074876; called by muse, mutect2, varscan2
- MGA | c.8602C>T p.P2868S (on ENST00000219905 / NM_001164273.1; = p.P2659S on NM_001080541.2) | Missense Mutation (SNP) | VAF 52/132 reads (39%) | SIFT tolerated (0.57); PolyPhen benign (0.006); catalogued as COSV54948997; called by muse, mutect2, varscan2
- MGA | c.8986G>A p.V2996I (on ENST00000219905 / NM_001164273.1; = p.V2787I on NM_001080541.2) | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.009); catalogued as COSV54965145; called by muse, mutect2, varscan2
- MGAM | c.2713C>T p.L905F | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0.107); catalogued as COSV72073978; called by muse, mutect2, varscan2
- MIP | c.226C>T p.L76F | Missense Mutation (SNP) | VAF 38/78 reads (49%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.846); catalogued as COSV57514320; called by muse, mutect2
- MIP | c.224T>A p.F75Y | Missense Mutation (SNP) | VAF 40/80 reads (50%) | SIFT tolerated (0.24); PolyPhen benign (0.067); catalogued as COSV57516174; called by muse, mutect2
- MMAA | c.1199C>T p.A400V | Missense Mutation (SNP) | VAF 32/69 reads (46%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as COSV55582366; called by muse, mutect2, varscan2
- MMRN2 | c.448G>A p.E150K | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.313); catalogued as rs1391183134, COSV64401546; called by muse, mutect2, varscan2
- MOB1B | c.344T>C p.I115T | Missense Mutation (SNP) | VAF 29/61 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); catalogued as COSV58675851; called by muse, mutect2, varscan2
- MOG | c.65del p.L22Pfs*13 | Frame Shift Del (DEL) | VAF 14/21 reads (67%) | catalogued as rs1554202088; called by mutect2, varscan2
- MORC4 | c.1744G>A p.E582K | Missense Mutation (SNP) | VAF 30/113 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.049); catalogued as COSV55247657; called by muse, mutect2, varscan2
- MPP1 | c.340G>T p.G114W | Missense Mutation (SNP) | VAF 38/193 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65728981; called by muse, mutect2, varscan2
- MROH8 | c.1486C>T p.P496S | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as COSV54126429; called by muse, mutect2, varscan2
- MSR1 | c.631G>A p.E211K | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT tolerated (0.27); PolyPhen benign (0.156); catalogued as rs939251648, COSV50543867; called by muse, mutect2, varscan2
- MUC16 | c.37075C>T p.P12359S | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.152); catalogued as rs562224893, COSV67460143; called by muse, mutect2, varscan2
- MUC2 | c.1597G>A p.G533S | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.47); PolyPhen benign (0.013); catalogued as rs201261465; called by muse, mutect2, varscan2
- MUC5B | c.13031C>T p.P4344L | Missense Mutation (SNP) | VAF 28/142 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV71591584, COSV71596669; called by muse, mutect2, varscan2
- MUC6 | c.2476G>A p.E826K | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.549); catalogued as rs755842554, COSV70151588; called by muse, mutect2, varscan2
- MXRA5 | c.3596C>T p.S1199F | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT tolerated (0.32); PolyPhen benign (0.086); catalogued as COSV54239171, COSV54254592; called by muse, mutect2, varscan2
- MYF5 | c.707C>T p.T236I | Missense Mutation (SNP) | VAF 58/89 reads (65%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs757659254, COSV57355707, COSV57357088; called by muse, mutect2, varscan2
- MYH15 | c.407C>T p.S136L | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV56307944; called by muse, mutect2, varscan2
- MYO15A | c.2822C>T p.S941F | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV52768615; called by muse, mutect2, varscan2
- NCAM2 | c.2260G>A p.E754K | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.268); catalogued as rs751165756, COSV53058235; called by muse, mutect2, varscan2
- NCOR1 | c.3113C>T p.P1038L | Missense Mutation (SNP) | VAF 30/83 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as COSV51988368, COSV51999724; called by muse, mutect2, varscan2
- NDST4 | c.34C>T p.R12* | Nonsense Mutation (SNP) | VAF 6/11 reads (55%) | catalogued as rs749271707, COSV52112958; called by muse, mutect2, varscan2
- NEURL4 | c.4277C>T p.A1426V | Missense Mutation (SNP) | VAF 46/112 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.043); catalogued as rs963778806, COSV59753905; called by muse, mutect2, varscan2
- NHS | c.2582C>A p.P861H | Missense Mutation (SNP) | VAF 54/124 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.799); catalogued as COSV66284827; called by muse, mutect2, varscan2
- NID2 | c.2731C>T p.P911S | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.988); catalogued as COSV53504302; called by muse, mutect2, varscan2
- NIT2 | c.620C>T p.S207F | Missense Mutation (SNP) | VAF 34/122 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV67630884; called by muse, mutect2, varscan2
- NLGN4X | c.1123G>A p.E375K | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52041438, COSV99319543; called by muse, mutect2, varscan2
- NLRP12 | c.1432G>A p.E478K | Missense Mutation (SNP) | VAF 38/113 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.387); catalogued as COSV60747324; called by muse, mutect2, varscan2
- NLRP12 | c.563G>A p.G188E | Missense Mutation (SNP) | VAF 31/83 reads (37%) | SIFT tolerated (0.6); PolyPhen benign (0.006); catalogued as COSV60743232; called by muse, mutect2, varscan2
- NLRP5 | c.2359G>A p.D787N | Missense Mutation (SNP) | VAF 29/92 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.882); catalogued as COSV66765368, COSV66768092; called by muse, mutect2, varscan2
- NOBOX | c.958G>A p.G320R | Missense Mutation (SNP) | VAF 23/79 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.458); catalogued as COSV56192504, COSV56198326, COSV56198634; called by muse, mutect2, varscan2
- NOL4 | c.1441C>T p.P481S | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV52353619; called by muse, mutect2, varscan2
- NOTCH4 | c.1300G>A p.D434N | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.106); catalogued as COSV66684647; called by muse, mutect2, varscan2
- NPEPL1 | c.1472C>T p.S491F | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.081); catalogued as COSV61940994; called by muse, mutect2, varscan2
- NPPC | c.169C>T p.P57S | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated (0.39); PolyPhen benign (0.007); catalogued as rs1274724785, COSV54945759; called by muse, mutect2
- NYX | c.1108G>A p.G370S | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.53); catalogued as COSV61182003; called by muse, mutect2, varscan2
- ODAM | c.532C>T p.P178S | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.451); catalogued as rs1330456894, COSV101258083; called by muse, mutect2, varscan2
- ODAM | c.533C>T p.P178L | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.934); catalogued as COSV101258085; called by muse, mutect2, varscan2
- OR10Q1 | c.709G>A p.E237K | Missense Mutation (SNP) | VAF 29/68 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.099); catalogued as rs772343084, COSV57472272; called by muse, mutect2, varscan2
- OR10W1 | c.358C>T p.P120S | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.762); catalogued as COSV67720994; called by muse, varscan2
- OR11H1 | c.467G>A p.G156E | Missense Mutation (SNP) | VAF 15/81 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV99421547; called by mutect2, varscan2
- OR2G6 | c.526C>T p.H176Y | Missense Mutation (SNP) | VAF 24/53 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58574109; called by muse, mutect2, varscan2
- OR3A2 | c.538C>T p.P180S | Missense Mutation (SNP) | VAF 26/117 reads (22%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.681); catalogued as COSV68695349; called by muse, mutect2, varscan2
- OR51I1 | c.786G>A p.M262I | Missense Mutation (SNP) | VAF 27/76 reads (36%) | SIFT tolerated (0.25); PolyPhen benign (0.037); catalogued as COSV66507955; called by muse, mutect2, varscan2
- OR51I2 | c.650C>T p.S217F | Missense Mutation (SNP) | VAF 42/127 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58297921; called by muse, mutect2, varscan2
- OR5P3 | c.85C>T p.L29F | Missense Mutation (SNP) | VAF 26/90 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.187); catalogued as COSV60430194; called by muse, mutect2, varscan2
- OR6C74 | c.194C>T p.S65L | Missense Mutation (SNP) | VAF 16/156 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.588); catalogued as COSV59607441, COSV59607561; called by muse, mutect2
- OTUD7A | c.1143G>A p.M381I (on ENST00000307050 / NM_001382637.1; = p.M374I on NM_130901.3) | Missense Mutation (SNP) | VAF 38/108 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV61044151; called by muse, mutect2, varscan2
- OTULIN | c.370C>T p.R124C | Missense Mutation (SNP) | VAF 39/114 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1240295700, COSV52504957; called by muse, mutect2, varscan2
- P4HA2 | c.1583C>T p.P528L | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); catalogued as COSV99387155; called by muse, mutect2, varscan2
- P4HA2 | c.1582C>T p.P528S | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.125); catalogued as COSV99387160; called by muse, mutect2, varscan2
- PARP8 | c.752T>A p.F251Y | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as COSV55868253; called by muse, mutect2, varscan2
- PCDHA4 | c.1672G>A p.E558K | Missense Mutation (SNP) | VAF 50/128 reads (39%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.926); catalogued as rs267600385, COSV63540193; called by muse, mutect2, varscan2
- PCDHB13 | c.1129G>A p.G377R | Missense Mutation (SNP) | VAF 39/129 reads (30%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.937); catalogued as COSV53395590, COSV53402238; called by muse, mutect2, varscan2
- PCDHB2 | c.646G>A p.A216T | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV52039183; called by muse, mutect2, varscan2
- PCOLCE2 | c.472C>T p.L158F | Missense Mutation (SNP) | VAF 20/98 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as rs1189032845, COSV56002758; called by muse, mutect2, varscan2
- PDCD1 | c.631G>A p.E211K | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.721); catalogued as rs775866946, COSV57691008; called by muse, mutect2, varscan2
- PDE3A | c.1199C>T p.S400L | Missense Mutation (SNP) | VAF 48/90 reads (53%) | SIFT tolerated (0.08); PolyPhen benign (0.026); catalogued as rs143792143; called by muse, mutect2, varscan2
- PDIA2 | c.616G>A p.D206N | Missense Mutation (SNP) | VAF 27/84 reads (32%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV51994916; called by muse, mutect2, varscan2
- PDLIM1 | c.235C>A p.L79I | Missense Mutation (SNP) | VAF 64/209 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.39); catalogued as COSV61474708, COSV61475252; called by muse, mutect2, varscan2
- PELP1 | c.1168C>T p.R390W | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.93); catalogued as rs762432194, COSV52588464; called by muse, mutect2, varscan2
- PHACTR2 | c.1724G>A p.R575Q | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.784); catalogued as rs750247740, COSV59860741; called by muse, mutect2, varscan2
- PIDD1 | c.484G>A p.E162K | Missense Mutation (SNP) | VAF 40/108 reads (37%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.777); catalogued as rs1403049852, COSV61707504; called by muse, mutect2, varscan2
- PIEZO2 | c.7945G>A p.E2649K | Missense Mutation (SNP) | VAF 40/79 reads (51%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.622); catalogued as rs761065211, COSV53286296; called by muse, mutect2, varscan2
- PIK3R6 | c.1108G>A p.G370R | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV100266325, COSV61006686; called by muse, mutect2, varscan2
- PJA1 | c.1025G>A p.R342Q (on ENST00000361478 / NM_145119.4; = p.R154Q on NM_022368.5) | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.968); catalogued as rs1359882967, COSV64053966; called by muse, mutect2, varscan2
- PKD1 | c.2420C>T p.S807F | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT tolerated (1); PolyPhen benign (0.062); catalogued as rs1222764731, COSV51927768; called by muse, mutect2, varscan2
- PKHD1 | c.2293G>A p.E765K | Missense Mutation (SNP) | VAF 29/98 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.154); catalogued as rs1554211410, COSV61898769; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PLA2R1 | c.1969G>A p.E657K | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as rs1369328710, COSV51788570; called by muse, mutect2, varscan2
- PLCE1 | c.289G>A p.D97N | Missense Mutation (SNP) | VAF 33/78 reads (42%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as COSV53376630; called by muse, mutect2, varscan2
- PLCE1 | c.3170G>A p.R1057Q | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.719); catalogued as rs754397478, COSV53376651; called by muse, mutect2, varscan2
- PLS3 | c.1307T>A p.I436N | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56782972; called by muse, mutect2, varscan2
- PLXDC2 | c.1073G>A p.G358E | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65905934; called by muse, mutect2, varscan2
- PLXNB3 | c.3326G>A p.R1109Q | Missense Mutation (SNP) | VAF 27/85 reads (32%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as rs145360535, COSV100737605; called by muse, mutect2, varscan2
- PNPLA7 | c.1802G>A p.R601Q | Missense Mutation (SNP) | VAF 29/83 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs765906182, COSV53008650; called by muse, mutect2, varscan2
- POR | c.104C>T p.S35L | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated (0.42); PolyPhen benign (0.005); catalogued as rs374350596; called by muse, mutect2, varscan2
- PRDM9 | c.698G>A p.G233E | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.808); catalogued as COSV57014897, COSV99691080; called by muse, mutect2, varscan2
- PREX2 | c.1382G>A p.R461K | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55786138, COSV55805592; called by muse, mutect2, varscan2
- PRKCH | c.613+1G>A p.X205_splice | Splice Site (SNP) | VAF 57/156 reads (37%) | catalogued as COSV60653350; called by muse, mutect2, varscan2
- PROC | c.765G>A p.M255I | Missense Mutation (SNP) | VAF 30/93 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.03); catalogued as rs754195274, COSV52168944; called by muse, mutect2, varscan2
- PRRC2B | c.3725C>T p.S1242F | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV100621930; called by muse, mutect2, varscan2
- PRUNE2 | c.6213G>A p.W2071* | Nonsense Mutation (SNP) | VAF 23/179 reads (13%) | catalogued as rs1411016488, COSV65044464, COSV65049496; called by muse, mutect2, varscan2
- PRUNE2 | c.1358G>A p.G453E | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV65049500; called by muse, mutect2, varscan2
- PTCH2 | c.782C>A p.P261Q | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64714035; called by muse, mutect2, varscan2
- PTCHD4 | c.1508C>T p.S503F | Missense Mutation (SNP) | VAF 3/45 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.966); catalogued as COSV59780639; called by muse, mutect2
- PTCRA | c.8G>A p.G3D | Missense Mutation (SNP) | VAF 35/195 reads (18%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.226); catalogued as COSV100485720, COSV58976994; called by muse, mutect2, varscan2
- PTPRT | c.1825G>T p.V609L | Missense Mutation (SNP) | VAF 24/190 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.213); catalogued as COSV62032504; called by muse, mutect2, varscan2
- PXDN | c.4324G>A p.G1442R | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1354620140, COSV53248624; called by muse, mutect2
- PXDNL | c.4003C>T p.H1335Y | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as COSV62501082; called by muse, mutect2
- PYGL | c.1147G>A p.E383K | Missense Mutation (SNP) | VAF 6/65 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV53589684; called by muse, mutect2
- R3HCC1L | c.1462G>A p.D488N | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100107412; called by muse, varscan2
- R3HCC1L | c.1463A>T p.D488V | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100107414; called by muse, varscan2
- RABGGTA | c.1612C>T p.L538F | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV52866042; called by muse, mutect2, varscan2
- RAG2 | c.1478G>A p.R493K | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs2037101, COSV57560302; called by muse, mutect2, varscan2
- RAI2 | c.780C>G p.F260L | Missense Mutation (SNP) | VAF 19/143 reads (13%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as COSV58966661; called by muse, mutect2, varscan2
- RALYL | c.284C>T p.P95L | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.951); catalogued as COSV72826772; called by muse, mutect2, varscan2
- RASGEF1C | c.662C>T p.P221L | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV63185507; called by muse, mutect2, varscan2
- RIF1 | c.6281C>T p.S2094F | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as COSV54617611; called by muse, mutect2, varscan2
- RIN1 | c.2104C>T p.R702C | Missense Mutation (SNP) | VAF 78/212 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.062); catalogued as rs370679290; called by muse, mutect2
- RPGRIP1 | c.2887C>T p.P963S | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as rs369202663; called by muse, mutect2, varscan2
- RPL3L | c.806C>T p.A269V | Missense Mutation (SNP) | VAF 38/110 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV51908878, COSV99237970; called by muse, mutect2, varscan2
- RPS6KA3 | c.479C>T p.S160F | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.997); catalogued as COSV65389801; called by muse, mutect2, varscan2
- RPTN | c.463G>A p.D155N | Missense Mutation (SNP) | VAF 150/432 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.135); catalogued as COSV60166131; called by muse, mutect2, varscan2
- RRP9 | c.1424C>T p.S475F | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.467); catalogued as COSV51756534; called by muse, mutect2, varscan2
- RSF1 | c.1832C>T p.P611L | Missense Mutation (SNP) | VAF 42/128 reads (33%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0); catalogued as COSV57847208; called by muse, mutect2, varscan2
- RUFY3 | c.181C>T p.P61S | Missense Mutation (SNP) | VAF 32/321 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.079); catalogued as COSV56918335; called by muse, mutect2
- RXFP1 | c.2264C>T p.S755F | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.401); catalogued as COSV57054978; called by muse, varscan2
- RYR3 | c.6709G>A p.G2237R | Missense Mutation (SNP) | VAF 43/150 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs921103094, COSV63109888; called by muse, mutect2, varscan2
- RYR3 | c.10169C>T p.S3390F (on ENST00000389232; = p.S3391F on NM_001036.6) | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.777); catalogued as rs1030065828, COSV66811716; called by muse, mutect2, varscan2
- SAMD14 | c.781C>T p.P261S | Missense Mutation (SNP) | VAF 49/135 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.629); catalogued as rs201226333, COSV50305413; called by muse, mutect2, varscan2
- SAMD9L | c.2533C>T p.P845S | Missense Mutation (SNP) | VAF 29/85 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs938001567, COSV59084806, COSV59086203; called by muse, mutect2, varscan2
- SCN8A | c.3439C>T p.P1147S | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT tolerated (0.34); PolyPhen benign (0.302); catalogued as COSV61994559; called by muse, mutect2, varscan2
- SCTR | c.511C>T p.H171Y | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.517); catalogued as COSV50029115; called by muse, mutect2, varscan2
- SECTM1 | c.641C>T p.S214F | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.014); catalogued as COSV53938203; called by muse, mutect2, varscan2
- SEL1L2 | c.856C>T p.Q286* | Nonsense Mutation (SNP) | VAF 15/48 reads (31%) | catalogued as COSV53154608, COSV53159685; called by muse, mutect2, varscan2
- SEMA4F | c.1913T>G p.V638G | Missense Mutation (SNP) | VAF 6/128 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.076); catalogued as COSV60285725; called by muse, mutect2
- SEMA6A | c.794C>T p.S265F | Missense Mutation (SNP) | VAF 27/86 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV57319278; called by muse, mutect2, varscan2
- SERP1 | c.123G>A p.W41* | Nonsense Mutation (SNP) | VAF 4/12 reads (33%) | catalogued as COSV99526542; called by muse, mutect2
- SERPINA10 | c.298T>A p.F100I | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT tolerated (0.3); PolyPhen benign (0.325); catalogued as COSV56230070; called by muse, mutect2
- SERPINA5 | c.721C>T p.Q241* | Nonsense Mutation (SNP) | VAF 10/30 reads (33%) | catalogued as COSV61575303; called by muse, mutect2, varscan2
- SETBP1 | c.1912G>A p.G638R | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT tolerated (0.19); PolyPhen benign (0.048); catalogued as COSV56340243; called by muse, mutect2, varscan2
- SEZ6L | c.863C>T p.P288L | Missense Mutation (SNP) | VAF 42/192 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50659587, COSV50700161; called by muse, mutect2, varscan2
- SH3RF2 | c.496G>A p.E166K | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.936); catalogued as rs757233835, COSV63037490; called by muse, mutect2, varscan2
- SH3TC1 | c.1852G>A p.E618K | Missense Mutation (SNP) | VAF 35/106 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.642); catalogued as COSV55291246; called by muse, mutect2, varscan2
- SIGLEC10 | c.1225G>A p.V409I | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT tolerated (0.23); PolyPhen benign (0.28); catalogued as rs1316255588, COSV59479938; called by muse, mutect2, varscan2
- SIGLEC8 | c.797G>A p.G266E | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT tolerated (0.74); PolyPhen benign (0.085); catalogued as COSV58474972; called by muse, mutect2, varscan2
- SLC22A9 | c.1111C>T p.H371Y | Missense Mutation (SNP) | VAF 23/91 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV54169391; called by muse, mutect2, varscan2
- SLC25A22 | c.656C>T p.S219F | Missense Mutation (SNP) | VAF 40/153 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.091); catalogued as COSV100204254; called by muse, mutect2, varscan2
- SLC26A11 | c.1097+1G>A p.X366_splice | Splice Site (SNP) | VAF 18/52 reads (35%) | catalogued as rs771088512, COSV63281560; called by muse, mutect2, varscan2
- SLC26A3 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 23/48 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.782); catalogued as COSV60643361; called by muse, mutect2, varscan2
- SLC26A4 | c.794G>A p.G265D | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT tolerated (0.51); PolyPhen benign (0.155); catalogued as rs775490005, COSV55920840; called by muse, mutect2, varscan2
- SLC26A8 | c.2638C>T p.R880W | Missense Mutation (SNP) | VAF 108/181 reads (60%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as rs1158010434, COSV62888136; called by muse, mutect2, varscan2
- SLC39A12 | c.208G>A p.E70K | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.345); catalogued as COSV66203184; called by muse, mutect2, varscan2
- SLC41A3 | c.1255G>A p.V419M | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59991253; called by muse, mutect2, varscan2
- SLC45A1 | c.1063G>A p.D355N | Missense Mutation (SNP) | VAF 17/32 reads (53%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as COSV57101777; called by muse, mutect2, varscan2
- SLFN11 | c.1455C>A p.D485E | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated (0.6); PolyPhen benign (0.034); catalogued as COSV57701002; called by muse, mutect2
- SLFN13 | c.1455C>A p.D485E | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as rs147071578, COSV99540148; called by mutect2, varscan2
- SMG6 | c.1361G>A p.R454Q | Missense Mutation (SNP) | VAF 20/248 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.127); catalogued as rs569275000, COSV53978450; called by muse, mutect2
- SNX13 | c.2717G>A p.R906K | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV68068886; called by muse, mutect2, varscan2
- SNX13 | c.840C>T p.I280= | Splice Region (SNP) | VAF 4/13 reads (31%) | catalogued as rs1317096421, COSV68068891; called by muse, mutect2, varscan2
- SORT1 | c.1649C>A p.S550Y | Missense Mutation (SNP) | VAF 10/17 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56671284; called by muse, mutect2, varscan2
- SOX30 | c.808G>A p.G270R | Missense Mutation (SNP) | VAF 29/92 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.982); catalogued as COSV53940140; called by muse, mutect2, varscan2
- SP110 | c.433C>T p.P145S | Missense Mutation (SNP) | VAF 56/151 reads (37%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.922); catalogued as COSV51281683; called by muse, mutect2, varscan2
- SPAG17 | c.1630C>T p.P544S | Missense Mutation (SNP) | VAF 23/42 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as COSV60463627; called by muse, mutect2, varscan2
- SPECC1 | c.685C>A p.L229I | Missense Mutation (SNP) | VAF 75/219 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54968232; called by muse, mutect2, varscan2
- TAF7 | c.347C>T p.P116L | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT tolerated (0.79); PolyPhen possibly damaging (0.773); catalogued as rs764209405, COSV57666403; called by muse, mutect2, varscan2
- TAOK1 | c.673T>A p.L225I | Missense Mutation (SNP) | VAF 23/81 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.9); catalogued as COSV55600325; called by muse, mutect2, varscan2
- TBC1D1 | c.2980G>A p.G994R | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54729119; called by muse, mutect2, varscan2
- TBC1D12 | c.1032G>A p.W344* | Nonsense Mutation (SNP) | VAF 19/52 reads (37%) | catalogued as COSV56559173; called by muse, mutect2, varscan2
- TBC1D14 | c.1207C>T p.P403S | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs868148286, COSV63391882; called by muse, mutect2, varscan2
- TBC1D22B | c.503C>T p.S168L | Missense Mutation (SNP) | VAF 20/105 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.028); catalogued as COSV65143772; called by muse, mutect2, varscan2
- TBCD | c.811C>T p.P271S | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.226); catalogued as COSV62809392; called by muse, mutect2, varscan2
- TBX1 | c.30G>A p.M10I | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.027); catalogued as COSV60355632; called by muse, mutect2, varscan2
- TCERG1 | c.578C>T p.A193V | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.009); catalogued as COSV57043034; called by muse, mutect2, varscan2
- TCHHL1 | c.2290C>T p.P764S | Missense Mutation (SNP) | VAF 43/120 reads (36%) | SIFT tolerated (0.32); PolyPhen benign (0.021); catalogued as COSV64285987; called by muse, mutect2, varscan2
- TDRD5 | c.1927G>A p.E643K | Missense Mutation (SNP) | VAF 28/90 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs867687242, COSV54242060; called by muse, mutect2, varscan2
- TECPR1 | c.3041C>T p.S1014F | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1180816829, COSV65785596; called by muse, mutect2, varscan2
- TET1 | c.347C>T p.S116F | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV65390390; called by muse, mutect2, varscan2
- TGM6 | c.9G>A p.G3= | Splice Region (SNP) | VAF 13/54 reads (24%) | catalogued as COSV52483563; called by muse, mutect2, varscan2
- TGM6 | c.1094G>A p.G365D | Missense Mutation (SNP) | VAF 43/141 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV52485270; called by muse, mutect2, varscan2
- TIGIT | c.304G>A p.D102N | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs146935299; called by muse, mutect2, varscan2
- TKT | c.1423C>T p.P475S | Missense Mutation (SNP) | VAF 31/96 reads (32%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.483); catalogued as COSV56247463; called by muse, mutect2, varscan2
- TLL1 | c.2540G>A p.R847Q | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.475); catalogued as rs867864770, COSV50339425; called by muse, mutect2, varscan2
- TLR3 | c.512A>G p.E171G | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.062); catalogued as COSV57170858; called by muse, mutect2, varscan2
- TLR3 | c.1516C>T p.R506C | Missense Mutation (SNP) | VAF 21/99 reads (21%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.464); catalogued as rs774735663, COSV57167543; called by muse, mutect2, varscan2
- TLR5 | c.1859C>T p.S620F | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV60561268; called by muse, mutect2, varscan2
- TLR8 | c.2999C>T p.S1000F (on ENST00000218032 / NM_138636.5; = p.S1018F on NM_016610.4) | Missense Mutation (SNP) | VAF 24/94 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54321582; called by muse, mutect2, varscan2
- TMC7 | c.1682C>T p.S561L | Missense Mutation (SNP) | VAF 163/455 reads (36%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.771); catalogued as rs1368519440, COSV58584209; called by muse, mutect2, varscan2
- TMEM177 | c.880C>T p.R294C | Missense Mutation (SNP) | VAF 44/132 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs746087035, COSV55609603; called by muse, mutect2, varscan2
- TMEM258 | c.170C>T p.S57F | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.085); catalogued as COSV53895180; called by muse, mutect2, varscan2
- TMEM259 | c.227C>T p.A76V | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV52264190; called by muse, mutect2, varscan2
- TMEM63C | c.625G>A p.G209R | Missense Mutation (SNP) | VAF 30/80 reads (38%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as rs758876190, COSV53610087; called by muse, mutect2, varscan2
- TMPRSS2 | c.1003C>T p.P335S | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.812); catalogued as COSV59828323; called by muse, mutect2, varscan2
- TRIM38 | c.188G>A p.R63Q | Missense Mutation (SNP) | VAF 23/90 reads (26%) | SIFT tolerated (0.2); PolyPhen benign (0.161); catalogued as rs779444009, COSV62643142; called by muse, mutect2, varscan2
- TRPC4AP | c.703T>A p.S235T | Missense Mutation (SNP) | VAF 18/162 reads (11%) | SIFT tolerated (0.57); PolyPhen benign (0.071); catalogued as COSV52685499; called by muse, mutect2, varscan2
- TRPC5 | c.790G>A p.E264K | Missense Mutation (SNP) | VAF 51/178 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53287023; called by muse, mutect2, varscan2
- TRUB1 | c.767G>A p.R256K | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53931514; called by muse, mutect2, varscan2
- TTC33 | c.442C>T p.R148* | Nonsense Mutation (SNP) | VAF 33/94 reads (35%) | catalogued as rs771094043, COSV61802268; called by muse, mutect2, varscan2
- TTLL4 | c.1940C>G p.S647C | Missense Mutation (SNP) | VAF 60/193 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.638); catalogued as COSV51440096; called by muse, mutect2, varscan2
- TTN | c.42062G>A p.R14021H (on ENST00000591111; = p.R6597H on NM_003319.4) | Missense Mutation (SNP) | VAF 11/38 reads (29%) | PolyPhen possibly damaging (0.847); catalogued as rs1457971549, COSV60418363; called by muse, mutect2, varscan2
- UBASH3B | c.487C>T p.P163S | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.751); catalogued as rs1412656284, COSV52503959; called by muse, mutect2, varscan2
- UGT1A4 | c.466C>T p.L156F | Missense Mutation (SNP) | VAF 60/180 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); catalogued as COSV100530455; called by muse, mutect2
- UGT1A9 | c.646G>A p.E216K | Missense Mutation (SNP) | VAF 84/231 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.692); catalogued as COSV60855274; called by muse, mutect2, varscan2
- USH2A | c.7399C>T p.P2467S | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.557); catalogued as COSV56453706; called by muse, mutect2, varscan2
- VIT | c.1886C>T p.A629V (on ENST00000389975 / NM_001177969.1; = p.A644V on NM_053276.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.874); catalogued as COSV64899842; called by muse, mutect2, varscan2
- VWA2 | c.1508C>T p.P503L | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.844); catalogued as rs1416075440, COSV53908981; called by muse, mutect2, varscan2
- VWF | c.6857G>A p.G2286E | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT tolerated (0.14); PolyPhen benign (0.272); catalogued as rs757486690, COSV54637870; called by muse, mutect2
- WDR33 | c.599C>T p.A200V | Missense Mutation (SNP) | VAF 60/167 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV59256824; called by muse, mutect2, varscan2
- XIRP2 | c.5740G>T p.V1914F (on ENST00000628543; = p.V2089F on NM_152381.6) | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.168); catalogued as COSV54741243; called by muse, mutect2, varscan2
- Z83844.2 | c.523C>T p.R175C | Missense Mutation (SNP) | VAF 31/50 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV60930206; called by muse, mutect2, varscan2
- ZFHX4 | c.7699C>T p.H2567Y | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT tolerated (1); PolyPhen possibly damaging (0.715); catalogued as COSV51502970, COSV99268479; called by muse, mutect2, varscan2
- ZFPM2 | c.296G>A p.G99E | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.457); catalogued as COSV68289862, COSV68292374; called by muse, mutect2
- ZFR2 | c.1346C>T p.P449L | Missense Mutation (SNP) | VAF 31/150 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs377697539; called by muse, mutect2, varscan2
- ZFR2 | c.1345C>T p.P449S | Missense Mutation (SNP) | VAF 31/149 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99507414; called by muse, mutect2, varscan2
- ZNF180 | c.1193C>T p.S398F | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.956); catalogued as rs1271459259, COSV55425216; called by muse, mutect2, varscan2
- ZNF214 | c.298C>T p.R100C | Missense Mutation (SNP) | VAF 145/405 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs375574205, COSV53480460; called by mutect2, varscan2
- ZNF217 | c.2795C>T p.P932L | Missense Mutation (SNP) | VAF 24/122 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.122); catalogued as rs1430355424, COSV56603651; called by muse, mutect2, varscan2
- ZNF292 | c.4093A>T p.K1365* | Nonsense Mutation (SNP) | VAF 8/12 reads (67%) | catalogued as COSV60548511; called by muse, mutect2, varscan2
- ZNF331 | c.385A>T p.N129Y | Missense Mutation (SNP) | VAF 22/83 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.143); catalogued as COSV53480892; called by muse, mutect2, varscan2
- ZNF415 | c.1384C>T p.H462Y | Missense Mutation (SNP) | VAF 38/121 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV54703463, COSV54706757; called by muse, mutect2, varscan2
- ZNF483 | c.1556G>A p.G519E | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.992); catalogued as COSV58517526; called by muse, mutect2, varscan2
- ZNF532 | c.1810C>T p.P604S | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60176394; called by muse, mutect2, varscan2
- ZNF560 | c.1779A>T p.R593S | Missense Mutation (SNP) | VAF 38/121 reads (31%) | SIFT tolerated (0.23); PolyPhen benign (0.156); catalogued as COSV56872667; called by muse, mutect2, varscan2
- ZNF610 | c.1327C>T p.L443F | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs375474425, COSV58347060; called by muse, mutect2, varscan2
- ZNF667 | c.739C>T p.H247Y | Missense Mutation (SNP) | VAF 28/96 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.368); catalogued as COSV52632981, COSV52634876; called by muse, mutect2, varscan2
- ZNF714 | c.1374T>G p.C458W | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV52516453; called by muse, mutect2, varscan2
- ZNF804B | c.1190G>A p.S397N | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as COSV60862929; called by muse, mutect2, varscan2
- ZUP1 | c.1055C>T p.S352F | Missense Mutation (SNP) | VAF 39/76 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs375114528, COSV63944141; called by muse, mutect2, varscan2
- ASPM | c.8957del p.G2986Vfs*7 | Frame Shift Del (DEL) | VAF 8/80 reads (10%) | called by mutect2, pindel
- NBPF11 | c.1882G>T p.E628* | Nonsense Mutation (SNP) | VAF 26/92 reads (28%) | called by muse, mutect2, varscan2
- NUTM2D | c.1578G>A p.M526I | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT tolerated (0.34); PolyPhen benign (0.007); called by mutect2, varscan2
- PIP4K2B | c.643T>C p.Y215H | Missense Mutation (SNP) | VAF 63/159 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- RXFP1 | c.2188_2190delinsTC p.P730Sfs*3 | Frame Shift Del (DEL) | VAF 27/84 reads (32%) | called by pindel, varscan2*
- TRAJ35 | c.55T>G p.L19V | Missense Mutation (SNP) | VAF 88/256 reads (34%) | called by muse, mutect2, varscan2
- UNC45B | c.1976_1996del p.A659_K665del | In Frame Del (DEL) | VAF 6/48 reads (13%) | called by mutect2, pindel
- ABCB7 | c.1875G>A p.K625= (on ENST00000373394 / NM_001271696.3; = p.K626= on NM_004299.6) | Silent (SNP) | VAF 13/48 reads (27%) | catalogued as COSV53724684; called by muse, mutect2, varscan2
- ACTR1B | c.915G>A p.T305= | Silent (SNP) | VAF 31/88 reads (35%) | catalogued as rs200672180, COSV56703194; called by muse, mutect2, varscan2
- ADAM12 | c.1191G>A p.R397= | Silent (SNP) | VAF 23/90 reads (26%) | catalogued as COSV64116365; called by muse, mutect2, varscan2
- ADAM20 | c.1623C>T p.F541= | Silent (SNP) | VAF 26/60 reads (43%) | catalogued as rs749257120, COSV56456949; called by muse, mutect2, varscan2
- ADAM29 | c.1464G>A p.K488= | Silent (SNP) | VAF 25/112 reads (22%) | catalogued as COSV63662505; called by muse, mutect2, varscan2
- ADAMTS8 | c.1881C>T p.C627= | Silent (SNP) | VAF 41/125 reads (33%) | catalogued as rs1191300221, COSV57298822; called by muse, mutect2, varscan2
- ADCY4 | c.1581C>T p.P527= | Silent (SNP) | VAF 13/43 reads (30%) | catalogued as COSV60258383; called by muse, mutect2, varscan2
- ADCY7 | c.774C>T p.D258= | Silent (SNP) | VAF 6/69 reads (9%) | catalogued as COSV54267053; called by muse, mutect2
- ADORA2A | c.249C>T p.F83= | Silent (SNP) | VAF 27/123 reads (22%) | catalogued as rs966769877, COSV58379641; called by muse, mutect2, varscan2
- ANK3 | c.9351C>T p.I3117= | Silent (SNP) | VAF 53/153 reads (35%) | catalogued as COSV55045291; called by muse, mutect2, varscan2
- ANKDD1A | c.289C>T p.L97= | Silent (SNP) | VAF 12/33 reads (36%) | catalogued as COSV60353197; called by muse, mutect2, varscan2
- ANKRD1 | c.385C>T p.L129= | Silent (SNP) | VAF 25/84 reads (30%) | catalogued as COSV63311259; called by muse, mutect2, varscan2
- APOB | c.8223C>T p.F2741= | Silent (SNP) | VAF 66/201 reads (33%) | catalogued as rs773868517, COSV51957803; called by muse, mutect2, varscan2
- APOC4 | c.303C>T p.F101= | Silent (SNP) | VAF 109/303 reads (36%) | catalogued as COSV52991077; called by muse, mutect2, varscan2
- AQP12A | c.357C>T p.L119= | Silent (SNP) | VAF 7/45 reads (16%) | catalogued as rs1440478454, COSV100538851; called by muse, mutect2, varscan2
- ASCL3 | c.192C>T p.I64= | Silent (SNP) | VAF 23/67 reads (34%) | catalogued as rs367626662; called by muse, mutect2, varscan2
- ASPH | c.1366T>C p.L456= | Silent (SNP) | VAF 17/48 reads (35%) | catalogued as COSV65248501; called by muse, mutect2, varscan2
- ASTN1 | c.627C>T p.I209= | Silent (SNP) | VAF 35/64 reads (55%) | catalogued as rs757444447, COSV56090618; called by muse, varscan2
- ATP1A3 | c.228C>T p.A76= (on ENST00000545399 / NM_001256214.2; = p.A63= on NM_152296.5) | Silent (SNP) | VAF 26/76 reads (34%) | catalogued as rs1555866073, COSV57489282, COSV57491980; called by muse, mutect2, varscan2
- ATP2B4 | c.3594A>G p.L1198= | Silent (SNP) | VAF 6/45 reads (13%) | catalogued as COSV58185438; called by muse, mutect2, varscan2
- BPTF | c.2223C>A p.V741= | Silent (SNP) | VAF 7/41 reads (17%) | catalogued as COSV100075271; called by muse, mutect2, varscan2
- BRINP1 | c.1692C>T p.V564= | Silent (SNP) | VAF 18/32 reads (56%) | catalogued as COSV56316024; called by muse, mutect2, varscan2
- C12orf54 | c.174G>A p.Q58= | Silent (SNP) | VAF 16/152 reads (11%) | catalogued as COSV58361320; called by muse, mutect2, varscan2
- C1R | c.501G>A p.G167= (on ENST00000536053 / NM_001354346.2; = p.G153= on NM_001733.7) | Silent (SNP) | VAF 25/80 reads (31%) | catalogued as COSV56927159; called by muse, mutect2, varscan2
- CACNA1C | c.2949C>T p.S983= | Silent (SNP) | VAF 16/77 reads (21%) | catalogued as COSV59784666; called by muse, mutect2, varscan2
- CACNG3 | c.489C>T p.D163= | Silent (SNP) | VAF 55/165 reads (33%) | catalogued as rs1387243846, COSV50087635; called by muse, mutect2, varscan2
- CAD | c.3657C>T p.V1219= | Silent (SNP) | VAF 62/194 reads (32%) | catalogued as COSV53033057; called by muse, mutect2, varscan2
- CAPN13 | c.1971G>A p.L657= | Silent (SNP) | VAF 4/28 reads (14%) | catalogued as COSV54434025; called by muse, mutect2
- CASR | c.84G>A p.K28= | Silent (SNP) | VAF 47/118 reads (40%) | catalogued as COSV56136559, COSV56142358; called by muse, mutect2, varscan2
- CCDC180 | c.687C>T p.S229= | Silent (SNP) | VAF 12/16 reads (75%) | catalogued as rs1307717645, COSV63836703; called by muse, mutect2, varscan2
- CD151 | c.510C>T p.I170= | Silent (SNP) | VAF 11/34 reads (32%) | catalogued as COSV58991379; called by muse, mutect2, varscan2
- CDADC1 | c.1134C>T p.F378= | Silent (SNP) | VAF 67/178 reads (38%) | catalogued as COSV51914244; called by muse, mutect2, varscan2
- CDH13 | c.1050G>A p.T350= | Silent (SNP) | VAF 80/217 reads (37%) | catalogued as rs369518166; called by muse, mutect2, varscan2
- CEACAM20 | c.1236G>A p.G412= | Silent (SNP) | VAF 4/12 reads (33%) | catalogued as rs759671570, COSV57603686; called by muse, mutect2
- CELSR3 | c.9594G>A p.S3198= | Silent (SNP) | VAF 10/42 reads (24%) | catalogued as rs547962497, COSV50845094; called by muse, mutect2, varscan2
- CES1 | c.21C>T p.I7= | Silent (SNP) | VAF 28/66 reads (42%) | catalogued as COSV62090997; called by muse, mutect2, varscan2
- CHRNA6 | c.1455G>A p.Q485= | Silent (SNP) | VAF 59/174 reads (34%) | catalogued as COSV52381452; called by muse, mutect2, varscan2
- CHST13 | c.960C>T p.F320= | Silent (SNP) | VAF 7/27 reads (26%) | catalogued as rs1236301960, COSV60043502; called by muse, mutect2
- CLPTM1L | c.675G>A p.L225= | Silent (SNP) | VAF 5/18 reads (28%) | catalogued as rs1416008868, COSV100307389, COSV57993456; called by muse, mutect2, varscan2
- COL4A1 | c.2313G>A p.A771= | Silent (SNP) | VAF 39/106 reads (37%) | catalogued as rs781701888, COSV65422895; ClinVar: likely benign; called by muse, mutect2, varscan2
- COL6A3 | c.2436G>A p.L812= | Silent (SNP) | VAF 27/90 reads (30%) | catalogued as rs939146803, COSV55103639; called by muse, mutect2
- CRP | c.372C>T p.I124= | Silent (SNP) | VAF 71/210 reads (34%) | catalogued as rs753294711, COSV54812508; called by muse, mutect2, varscan2
- CTTNBP2 | c.3681C>T p.F1227= | Silent (SNP) | VAF 15/58 reads (26%) | catalogued as COSV50499049; called by muse, mutect2, varscan2
- CTXN3 | c.39C>T p.P13= | Silent (SNP) | VAF 27/60 reads (45%) | catalogued as rs199834318, COSV65218994; called by muse, mutect2, varscan2
- CYFIP1 | c.2469C>T p.A823= | Silent (SNP) | VAF 22/85 reads (26%) | called by muse, mutect2, varscan2
- DARS1 | c.579G>A p.Q193= | Silent (SNP) | VAF 3/38 reads (8%) | called by muse, mutect2
- DCAF1 | c.651C>T p.D217= | Silent (SNP) | VAF 75/231 reads (32%) | catalogued as COSV60047438; called by muse, mutect2, varscan2
- DGKZ | c.768C>A p.P256= (on ENST00000454345 / NM_001105540.2; = p.P67= on NM_003646.4) | Silent (SNP) | VAF 25/86 reads (29%) | catalogued as COSV58995300, COSV58997325; called by muse, mutect2, varscan2
- DMRTA2 | c.897C>T p.A299= | Silent (SNP) | VAF 47/92 reads (51%) | catalogued as COSV68673208; called by muse, mutect2, varscan2
- DNAH17 | c.12498C>A p.V4166= | Silent (SNP) | VAF 13/50 reads (26%) | catalogued as COSV53149375; called by muse, mutect2, varscan2
- DNAH5 | c.7893G>A p.T2631= | Silent (SNP) | VAF 9/36 reads (25%) | catalogued as rs371810104; called by muse, mutect2, varscan2
- DNAH7 | c.7272C>T p.L2424= | Silent (SNP) | VAF 15/47 reads (32%) | catalogued as COSV56753152, COSV56753936, COSV56754466; called by muse, mutect2, varscan2
- DUSP8 | c.729C>T p.I243= | Silent (SNP) | VAF 19/60 reads (32%) | catalogued as rs753062218, COSV59031695; called by muse, mutect2, varscan2
- DYTN | c.1527G>A p.K509= | Silent (SNP) | VAF 26/100 reads (26%) | catalogued as COSV71753195; called by muse, mutect2, varscan2
- EFCAB12 | c.1281C>T p.F427= | Silent (SNP) | VAF 50/110 reads (45%) | catalogued as rs1043099592, COSV58179415; called by muse, mutect2, varscan2
- ELMO1 | c.903C>T p.T301= | Silent (SNP) | VAF 15/51 reads (29%) | catalogued as COSV60330258; called by muse, mutect2, varscan2
- EPPK1 | c.3738C>T p.G1246= | Silent (SNP) | VAF 7/14 reads (50%) | catalogued as rs1554660373, COSV73262500; called by muse, mutect2, varscan2
- ESR2 | c.1542G>A p.P514= | Silent (SNP) | VAF 14/63 reads (22%) | catalogued as rs374713642, COSV50840044; ClinVar: likely benign; called by muse, mutect2, varscan2
- EVC2 | c.2220C>T p.T740= | Silent (SNP) | VAF 20/78 reads (26%) | catalogued as COSV60405253; called by muse, mutect2, varscan2
- EXOSC4 | c.546C>T p.G182= | Silent (SNP) | VAF 22/73 reads (30%) | catalogued as COSV100284117; called by muse, mutect2, varscan2
- FAM135B | c.2181C>T p.S727= | Silent (SNP) | VAF 8/36 reads (22%) | catalogued as COSV52759036; called by muse, mutect2
- FBN2 | c.6105G>A p.L2035= | Silent (SNP) | VAF 25/62 reads (40%) | catalogued as COSV52551526; called by muse, mutect2, varscan2
- FBN3 | c.7923C>T p.F2641= | Silent (SNP) | VAF 39/104 reads (38%) | catalogued as COSV54465915; called by muse, mutect2, varscan2
- FBN3 | c.4023C>T p.V1341= | Silent (SNP) | VAF 17/61 reads (28%) | catalogued as rs1445534857, COSV54476099; called by muse, mutect2, varscan2
- FBP1 | c.360C>T p.P120= | Silent (SNP) | VAF 11/43 reads (26%) | catalogued as COSV64690240; called by muse, mutect2, varscan2
- FLNA | c.411C>T p.I137= | Silent (SNP) | VAF 40/207 reads (19%) | catalogued as COSV61053549; called by muse, mutect2, varscan2
- FOLH1 | c.594G>A p.G198= | Silent (SNP) | VAF 16/56 reads (29%) | catalogued as COSV57045962; called by muse, mutect2, varscan2
- FPGS | c.567C>T p.F189= | Silent (SNP) | VAF 57/156 reads (37%) | catalogued as COSV64676350; called by muse, mutect2, varscan2
- FRAS1 | c.4578C>T p.I1526= | Silent (SNP) | VAF 92/239 reads (38%) | catalogued as rs757959583, COSV53658312; called by muse, mutect2, varscan2
- FRMPD1 | c.4620G>A p.S1540= | Silent (SNP) | VAF 68/222 reads (31%) | catalogued as rs138810329; called by muse, mutect2, varscan2
- FSHB | c.6G>A p.K2= | Silent (SNP) | VAF 10/44 reads (23%) | catalogued as rs770330659, COSV54223023; ClinVar: likely benign; called by muse, mutect2, varscan2
- GAS2L2 | c.2400C>T p.A800= | Silent (SNP) | VAF 62/137 reads (45%) | called by muse, mutect2, varscan2
- GATA2 | c.1419C>T p.S473= | Silent (SNP) | VAF 6/36 reads (17%) | catalogued as COSV62007943; called by muse, mutect2, varscan2
- GDPD5 | c.1470C>T p.I490= | Silent (SNP) | VAF 17/37 reads (46%) | catalogued as COSV61130905; called by muse, mutect2, varscan2
- GLT6D1 | c.141G>A p.T47= | Silent (SNP) | VAF 36/106 reads (34%) | catalogued as rs367832463, COSV65628435; called by muse, varscan2
- GNAI2 | c.294C>T p.P98= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as rs1553702650, COSV56496215; called by muse, mutect2
- GNAZ | c.237C>T p.D79= | Silent (SNP) | VAF 45/326 reads (14%) | catalogued as COSV50742958, COSV99321355; called by muse, mutect2, varscan2
- GNB2 | c.957G>A p.G319= | Silent (SNP) | VAF 19/60 reads (32%) | catalogued as COSV99309643; called by muse, mutect2, varscan2
- GPATCH2 | c.192G>A p.Q64= | Silent (SNP) | VAF 39/110 reads (35%) | catalogued as COSV65128797; called by muse, mutect2, varscan2
- GPR39 | c.339C>T p.F113= | Silent (SNP) | VAF 25/68 reads (37%) | catalogued as COSV61430585; called by muse, mutect2, varscan2
- GPRC5D | c.477G>A p.V159= | Silent (SNP) | VAF 32/62 reads (52%) | catalogued as rs755910423, COSV57433652; called by muse, mutect2, varscan2
- GREB1 | c.4084C>T p.L1362= | Silent (SNP) | VAF 35/121 reads (29%) | catalogued as COSV52198525; called by muse, mutect2, varscan2
- GRID2 | c.492C>T p.A164= | Silent (SNP) | VAF 20/92 reads (22%) | catalogued as COSV99942829; called by muse, mutect2, varscan2
- GSTA2 | c.651G>A p.R217= | Silent (SNP) | VAF 17/110 reads (15%) | catalogued as rs753132704, COSV72415686; called by muse, mutect2, varscan2
- HECW2 | c.2514G>A p.P838= | Silent (SNP) | VAF 30/63 reads (48%) | catalogued as rs200575058; called by muse, mutect2, varscan2
- HIF3A | c.1158C>T p.P386= (on ENST00000377670 / NM_152795.4; = p.P317= on NM_022462.4) | Silent (SNP) | VAF 86/207 reads (42%) | catalogued as rs1270894674, COSV52206024; called by muse, mutect2, varscan2
- HINT2 | c.186G>A p.K62= | Silent (SNP) | VAF 25/64 reads (39%) | catalogued as COSV52416136; called by muse, mutect2, varscan2
- HIVEP1 | c.501C>T p.S167= | Silent (SNP) | VAF 37/259 reads (14%) | catalogued as COSV101045310; called by muse, mutect2, varscan2
- HOGA1 | c.60G>A p.R20= | Silent (SNP) | VAF 17/144 reads (12%) | catalogued as rs776319977, COSV53970018; called by muse, mutect2, varscan2
- HTR7 | c.720G>A p.T240= | Silent (SNP) | VAF 23/67 reads (34%) | catalogued as rs1262632501, COSV53284926; called by muse, mutect2, varscan2
- IGHG3 | c.552C>T p.S184= | Silent (SNP) | VAF 40/117 reads (34%) | called by muse, mutect2, varscan2
- IGHG3 | c.159C>T p.F53= | Silent (SNP) | VAF 18/51 reads (35%) | called by muse, mutect2, varscan2
- IGKV6D-41 | c.240G>A p.S80= | Silent (SNP) | VAF 28/79 reads (35%) | catalogued as rs367937370; called by muse, mutect2, varscan2
- IL17RD | c.1908C>T p.A636= | Silent (SNP) | VAF 8/30 reads (27%) | catalogued as rs368367323, COSV56344156; called by muse, varscan2
- ITGAM | c.1431C>T p.I477= | Silent (SNP) | VAF 67/170 reads (39%) | catalogued as rs930496231, COSV54943921; called by muse, mutect2, varscan2
- KCNA4 | c.306C>T p.F102= | Silent (SNP) | VAF 11/41 reads (27%) | catalogued as COSV60256691; called by muse, mutect2, varscan2
- KCNN3 | c.654G>A p.E218= | Silent (SNP) | VAF 17/59 reads (29%) | catalogued as COSV55228945; called by muse, mutect2, varscan2
- KRAS | c.180T>G p.G60= | Silent (SNP) | VAF 39/81 reads (48%) | catalogued as COSV55499291, COSV55523567, COSV99782811; called by muse, mutect2, varscan2
- KRT5 | c.1683G>T p.L561= | Silent (SNP) | VAF 6/70 reads (9%) | catalogued as COSV52864089; called by muse, mutect2
- KRT78 | c.807C>T p.S269= | Silent (SNP) | VAF 12/88 reads (14%) | catalogued as COSV58854104; called by muse, mutect2, varscan2
- KRTAP12-4 | c.120C>T p.P40= | Silent (SNP) | VAF 6/29 reads (21%) | catalogued as COSV59983788; called by muse, mutect2, varscan2
- LAMA5 | c.2736C>T p.V912= | Silent (SNP) | VAF 17/63 reads (27%) | catalogued as COSV99440958; called by muse, mutect2, varscan2
- LGALS9B | c.837C>T p.V279= (on ENST00000423676 / NM_001367292.1; = p.V278= on NM_001042685.2) | Silent (SNP) | VAF 19/54 reads (35%) | catalogued as COSV60866105; called by muse, mutect2, varscan2
- LIPJ | c.627C>T p.F209= | Silent (SNP) | VAF 29/101 reads (29%) | catalogued as rs751090349, COSV64245154, COSV64245189; called by muse, mutect2, varscan2
- LRP3 | c.2217C>T p.P739= | Silent (SNP) | VAF 4/15 reads (27%) | catalogued as COSV53508011; called by muse, mutect2
- LRRC30 | c.273G>A p.G91= | Silent (SNP) | VAF 11/40 reads (28%) | catalogued as COSV67301300; called by muse, mutect2, varscan2
- LRTM1 | c.669G>A p.R223= | Silent (SNP) | VAF 10/25 reads (40%) | catalogued as COSV55546789; called by muse, mutect2, varscan2
- MAGEA3 | c.750C>T p.F250= | Silent (SNP) | VAF 43/162 reads (27%) | catalogued as rs782271747, COSV64756293; called by muse, mutect2, varscan2
- MANBA | c.1260C>T p.L420= (on ENST00000642252; = p.L374= on NM_005908.4) | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as COSV56971621, COSV99898527; called by muse, mutect2, varscan2
- MAP3K15 | c.1314G>A p.G438= | Silent (SNP) | VAF 10/29 reads (34%) | catalogued as COSV58840516; called by muse, mutect2, varscan2
- ME1 | c.1434C>T p.F478= | Silent (SNP) | VAF 11/31 reads (35%) | catalogued as COSV63843299; called by muse, mutect2, varscan2
- MGAM | c.2292C>T p.L764= | Silent (SNP) | VAF 4/24 reads (17%) | catalogued as rs1009720283, COSV72075164, COSV72076159; called by muse, mutect2
- MLH1 | c.741C>T p.S247= | Silent (SNP) | VAF 12/39 reads (31%) | catalogued as rs876660242, COSV51625810; ClinVar: likely benign; called by muse, mutect2, varscan2
- MRC1 | c.1722G>A p.G574= | Silent (SNP) | VAF 42/154 reads (27%) | called by muse, mutect2, varscan2
- MRPL46 | c.805C>T p.L269= | Silent (SNP) | VAF 27/81 reads (33%) | catalogued as rs780339619, COSV56901302; called by muse, mutect2, varscan2
- MTFR1 | c.441C>T p.L147= | Silent (SNP) | VAF 4/13 reads (31%) | catalogued as rs144568946; called by muse, mutect2, varscan2
- MTMR11 | c.1413C>T p.T471= (on ENST00000439741 / NM_001145862.2; = p.T399= on NM_181873.3) | Silent (SNP) | VAF 12/36 reads (33%) | catalogued as rs1046447370, COSV54967299; called by muse, mutect2, varscan2
- MUC16 | c.34011G>T p.V11337= | Silent (SNP) | VAF 12/136 reads (9%) | catalogued as COSV67502361; called by muse, mutect2
- MUC16 | c.28383C>T p.V9461= | Silent (SNP) | VAF 34/95 reads (36%) | catalogued as rs147088301, COSV67502364; called by muse, mutect2, varscan2
- MUC16 | c.25419C>T p.I8473= | Silent (SNP) | VAF 65/185 reads (35%) | catalogued as COSV67502366; called by muse, mutect2, varscan2
- MUC16 | c.3489C>A p.P1163= | Silent (SNP) | VAF 21/71 reads (30%) | catalogued as rs747792324, COSV67502368; called by muse, mutect2, varscan2
- MUC17 | c.7533T>C p.S2511= | Silent (SNP) | VAF 141/372 reads (38%) | catalogued as COSV60307546; called by muse, mutect2, varscan2
- MYH10 | c.1209C>T p.V403= | Silent (SNP) | VAF 14/40 reads (35%) | catalogued as rs760755512, COSV52613847; called by muse, mutect2, varscan2
- MYO18B | c.573G>A p.K191= | Silent (SNP) | VAF 6/15 reads (40%) | catalogued as rs746410479, COSV59132422, COSV59150504; called by muse, mutect2, varscan2
- MYOM1 | c.2019G>A p.V673= | Silent (SNP) | VAF 16/76 reads (21%) | catalogued as COSV55303122; called by muse, mutect2, varscan2
- NAALADL2 | c.2319T>A p.I773= | Silent (SNP) | VAF 10/34 reads (29%) | catalogued as COSV71987490; called by muse, mutect2, varscan2
- NAP1L2 | c.591G>A p.V197= | Silent (SNP) | VAF 12/35 reads (34%) | catalogued as COSV65173195; called by muse, mutect2, varscan2
- NCAPD3 | c.900C>T p.F300= | Silent (SNP) | VAF 16/70 reads (23%) | catalogued as COSV73259063; called by muse, mutect2, varscan2
- NEB | c.11691G>A p.Q3897= | Silent (SNP) | VAF 24/76 reads (32%) | catalogued as COSV51468265; called by muse, mutect2, varscan2
- NFATC4 | c.1191C>T p.I397= | Silent (SNP) | VAF 9/44 reads (20%) | catalogued as COSV51613755; called by muse, mutect2, varscan2
- NLRP10 | c.978C>T p.S326= | Silent (SNP) | VAF 45/118 reads (38%) | catalogued as COSV60780853, COSV60783293; called by muse, mutect2, varscan2
- NLRP7 | c.999C>T p.F333= | Silent (SNP) | VAF 14/48 reads (29%) | catalogued as rs1327913215, COSV100051496, COSV60176692; called by muse, mutect2, varscan2
- NOS3 | c.2205C>T p.Y735= | Silent (SNP) | VAF 5/30 reads (17%) | catalogued as COSV52497066; called by muse, mutect2, varscan2
- NOTCH3 | c.2292C>T p.V764= | Silent (SNP) | VAF 27/75 reads (36%) | catalogued as COSV54654489; called by muse, mutect2, varscan2
- NPAP1 | c.852G>A p.E284= | Silent (SNP) | VAF 24/61 reads (39%) | catalogued as COSV61504365, COSV61512570; called by muse, mutect2, varscan2
- NPAP1 | c.3216G>A p.G1072= | Silent (SNP) | VAF 27/77 reads (35%) | catalogued as COSV61512575; called by muse, mutect2, varscan2
- NPTN | c.759G>A p.Q253= | Silent (SNP) | VAF 27/63 reads (43%) | catalogued as COSV54740674; called by muse, mutect2, varscan2
- OR2T2 | c.810G>A p.E270= | Silent (SNP) | VAF 13/74 reads (18%) | catalogued as COSV100737719, COSV61617836; called by muse, mutect2, varscan2
- OR51F2 | c.192C>T p.F64= | Silent (SNP) | VAF 61/166 reads (37%) | catalogued as rs557130556, COSV100437960, COSV59066362; called by muse, mutect2, varscan2
- OR51L1 | c.645C>T p.F215= | Silent (SNP) | VAF 16/54 reads (30%) | catalogued as rs769957998, COSV58626099; called by muse, mutect2, varscan2
- OR52M1 | c.129G>A p.G43= | Silent (SNP) | VAF 22/63 reads (35%) | catalogued as rs1041899797, COSV64173159; called by muse, mutect2, varscan2
- PAK5 | c.210C>T p.I70= | Silent (SNP) | VAF 52/116 reads (45%) | catalogued as rs1215112829, COSV62040403; called by muse, mutect2, varscan2
- PALB2 | c.870G>A p.E290= | Silent (SNP) | VAF 36/110 reads (33%) | catalogued as rs761771287, COSV55165106; ClinVar: likely benign; called by muse, mutect2, varscan2
- PALD1 | c.750G>A p.T250= | Silent (SNP) | VAF 41/120 reads (34%) | catalogued as rs373712496; called by muse, mutect2, varscan2
- PAPPA2 | c.3354G>A p.G1118= | Silent (SNP) | VAF 16/50 reads (32%) | catalogued as rs1553394103, COSV100868537, COSV62814702; called by muse, mutect2, varscan2
- PCDHA6 | c.807G>A p.R269= | Silent (SNP) | VAF 42/182 reads (23%) | catalogued as COSV65348888, COSV65359453; called by muse, mutect2, varscan2
- PCDHB14 | c.2124C>T p.F708= | Silent (SNP) | VAF 66/181 reads (36%) | catalogued as COSV53391301; called by muse, mutect2, varscan2
- PCDHB8 | c.1482C>T p.P494= | Silent (SNP) | VAF 79/687 reads (11%) | catalogued as COSV50830813; called by muse, mutect2, varscan2
- PCDHGB1 | c.390C>T p.F130= | Silent (SNP) | VAF 15/106 reads (14%) | catalogued as rs374865865, COSV53896802; called by muse, mutect2, varscan2
- PDS5A | c.2166C>T p.P722= | Silent (SNP) | VAF 12/33 reads (36%) | catalogued as COSV57832577; called by muse, mutect2, varscan2
- PDZD4 | c.138G>A p.V46= | Silent (SNP) | VAF 4/26 reads (15%) | catalogued as COSV51252997; called by muse, mutect2, varscan2
- PEG3 | c.3531C>T p.F1177= | Silent (SNP) | VAF 43/131 reads (33%) | catalogued as COSV55626665; called by muse, mutect2, varscan2
- PELP1 | c.2043C>T p.G681= | Silent (SNP) | VAF 29/83 reads (35%) | catalogued as rs1261976983, COSV52593419; called by muse, mutect2, varscan2
- PIK3R4 | c.2362C>T p.L788= | Silent (SNP) | VAF 25/70 reads (36%) | catalogued as COSV63244656; called by muse, mutect2, varscan2
- PKN3 | c.1488C>T p.F496= | Silent (SNP) | VAF 13/83 reads (16%) | catalogued as COSV52580312; called by muse, mutect2, varscan2
- PLIN1 | c.555G>A p.E185= | Silent (SNP) | VAF 6/16 reads (38%) | catalogued as rs748797937, COSV55585624; called by muse, varscan2
- PLXNB3 | c.3327G>A p.R1109= | Silent (SNP) | VAF 28/87 reads (32%) | catalogued as COSV100737606; called by muse, mutect2, varscan2
- POLR1B | c.2343C>T p.L781= | Silent (SNP) | VAF 29/69 reads (42%) | catalogued as rs1459398809, COSV54504786; called by muse, mutect2, varscan2
- POLR3A | c.2916C>T p.F972= | Silent (SNP) | VAF 18/69 reads (26%) | catalogued as rs763107166, COSV64931439, COSV64931461; called by muse, mutect2, varscan2
- POTEE | c.2778G>A p.E926= | Silent (SNP) | VAF 26/366 reads (7%) | catalogued as COSV58247797; called by muse, mutect2
- POU2F2 | c.747G>A p.L249= (on ENST00000526816 / NM_001207025.3; = p.L233= on NM_002698.5) | Silent (SNP) | VAF 41/116 reads (35%) | catalogued as rs1405650998, COSV60767311; called by muse, mutect2, varscan2
- PPFIA3 | c.1776C>T p.S592= | Silent (SNP) | VAF 6/12 reads (50%) | catalogued as rs1380252611, COSV61951509; called by muse, mutect2, varscan2
- PPP1R15A | c.777C>T p.S259= | Silent (SNP) | VAF 22/56 reads (39%) | catalogued as COSV52340472; called by muse, mutect2, varscan2
- PPP2R3A | c.2904A>G p.E968= | Silent (SNP) | VAF 18/45 reads (40%) | catalogued as rs1370435450, COSV53872323; called by muse, mutect2, varscan2
- PRDM15 | c.2235C>T p.N745= | Silent (SNP) | VAF 25/118 reads (21%) | catalogued as rs1568921286, COSV54161064; called by muse, mutect2, varscan2
- PRPF8 | c.2383C>T p.L795= | Silent (SNP) | VAF 77/218 reads (35%) | catalogued as COSV59268887; called by muse, mutect2, varscan2
- PRRC2B | c.3726C>T p.S1242= | Silent (SNP) | VAF 8/25 reads (32%) | catalogued as rs374219548; called by muse, mutect2, varscan2
- PTPRN | c.2670C>T p.F890= | Silent (SNP) | VAF 3/16 reads (19%) | catalogued as COSV55353128; called by muse, mutect2
- PTPRT | c.2781C>T p.S927= | Silent (SNP) | VAF 16/70 reads (23%) | catalogued as COSV62025829; called by muse, mutect2, varscan2
- R3HCC1L | c.1461G>A p.L487= | Silent (SNP) | VAF 16/58 reads (28%) | catalogued as COSV100107411; called by muse, varscan2
- RAB3D | c.261C>T p.I87= | Silent (SNP) | VAF 57/180 reads (32%) | catalogued as rs749887813, COSV55793328; called by muse, mutect2, varscan2
- RAD50 | c.381C>T p.V127= | Silent (SNP) | VAF 18/39 reads (46%) | catalogued as COSV54758693; called by muse, mutect2, varscan2
- RDH12 | c.129G>A p.V43= | Silent (SNP) | VAF 22/89 reads (25%) | catalogued as COSV50823558; called by muse, mutect2, varscan2
- RPAP3 | c.1521C>T p.S507= | Silent (SNP) | VAF 12/122 reads (10%) | catalogued as rs752794767, COSV50043296; called by muse, mutect2
- RPL7L1 | c.76C>T p.L26= | Silent (SNP) | VAF 19/89 reads (21%) | catalogued as rs1046766455, COSV100491780, COSV59034927, COSV59035899; called by muse, mutect2, varscan2
- RRAGB | c.1065G>A p.R355= (on ENST00000262850 / NM_016656.4; = p.R327= on NM_006064.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 6/29 reads (21%) | catalogued as COSV53332337; called by muse, mutect2, varscan2
- RYR3 | c.6708G>A p.G2236= | Silent (SNP) | VAF 42/148 reads (28%) | catalogued as rs1485101035, COSV63109671; ClinVar: likely benign; called by muse, mutect2, varscan2
- SCARF1 | c.2049G>A p.E683= | Silent (SNP) | VAF 13/47 reads (28%) | catalogued as COSV53961928; called by muse, mutect2, varscan2
- SH3TC1 | c.552G>A p.E184= | Silent (SNP) | VAF 11/25 reads (44%) | catalogued as COSV55291231; called by muse, mutect2, varscan2
- SIN3B | c.315C>T p.P105= | Silent (SNP) | VAF 46/133 reads (35%) | catalogued as rs1470624905, COSV56137213; called by muse, mutect2, varscan2
- SLC6A8 | c.1311C>T p.Y437= | Silent (SNP) | VAF 46/102 reads (45%) | catalogued as COSV53473858; called by muse, mutect2, varscan2
- SMU1 | c.444C>T p.A148= | Silent (SNP) | VAF 10/31 reads (32%) | catalogued as rs1039977579, COSV68140520; called by muse, mutect2, varscan2
- SOX7 | c.399C>T p.F133= | Silent (SNP) | VAF 8/36 reads (22%) | catalogued as rs751825913, COSV58731981; called by muse, mutect2, varscan2
- SPNS3 | c.358C>T p.L120= | Silent (SNP) | VAF 36/116 reads (31%) | catalogued as COSV61072696; called by muse, mutect2, varscan2
- SRC | c.60C>T p.P20= | Silent (SNP) | VAF 25/67 reads (37%) | catalogued as rs1191370735, COSV62441567; called by muse, mutect2, varscan2
- SREBF1 | c.433C>T p.L145= | Silent (SNP) | VAF 15/40 reads (38%) | catalogued as COSV55420888; called by muse, mutect2, varscan2
- STC2 | c.387G>A p.R129= | Silent (SNP) | VAF 10/33 reads (30%) | catalogued as rs755255816, COSV54181400; called by muse, mutect2, varscan2
- STIM1 | c.1317C>T p.F439= | Silent (SNP) | VAF 21/68 reads (31%) | catalogued as rs1179975549, COSV56161845; called by muse, mutect2, varscan2
- SYNGR1 | c.129C>T p.I43= | Silent (SNP) | VAF 13/103 reads (13%) | catalogued as rs762377335, COSV53369509; called by muse, mutect2, varscan2
- TAF1L | c.1215G>A p.R405= | Silent (SNP) | VAF 42/189 reads (22%) | catalogued as rs373288483; called by muse, mutect2, varscan2
- TANC1 | c.2415G>A p.R805= | Silent (SNP) | VAF 13/129 reads (10%) | catalogued as COSV55099797; called by muse, mutect2
- TECTA | c.6153C>T p.S2051= | Silent (SNP) | VAF 24/93 reads (26%) | catalogued as COSV50839301; called by muse, mutect2, varscan2
- THRSP | c.396G>A p.Q132= | Silent (SNP) | VAF 3/21 reads (14%) | catalogued as COSV55247210; called by muse, mutect2
- THSD4 | c.978C>T p.F326= | Silent (SNP) | VAF 43/142 reads (30%) | catalogued as COSV55976955, COSV55988406; called by muse, mutect2, varscan2
- THSD7B | c.1302G>A p.G434= | Silent (SNP) | VAF 13/32 reads (41%) | catalogued as rs1227132641, COSV55720777, COSV55726576; called by muse, mutect2, varscan2
- TKTL2 | c.1038G>A p.T346= | Silent (SNP) | VAF 36/95 reads (38%) | catalogued as rs755814436, COSV54921058; called by muse, mutect2, varscan2
- TRERF1 | c.1311G>A p.A437= | Silent (SNP) | VAF 130/182 reads (71%) | catalogued as rs778207579, COSV61679340; called by muse, mutect2, varscan2
- TRIM5 | c.138C>T p.S46= | Silent (SNP) | VAF 28/114 reads (25%) | catalogued as rs1268353086, COSV59902659; called by muse, mutect2, varscan2
- TRMT1 | c.960C>T p.F320= | Silent (SNP) | VAF 17/47 reads (36%) | catalogued as COSV55568175; called by muse, mutect2, varscan2
- TRPV1 | c.792C>T p.I264= | Silent (SNP) | VAF 4/13 reads (31%) | catalogued as rs753718104, COSV51517975; called by muse, mutect2, varscan2
- TSC22D2 | c.408C>T p.G136= | Silent (SNP) | VAF 19/52 reads (37%) | catalogued as rs1366654808, COSV62623859; called by muse, mutect2, varscan2
- TSHZ1 | c.2196C>T p.I732= (on ENST00000580243 / NM_001308210.2; = p.I687= on NM_005786.6) | Silent (SNP) | VAF 10/32 reads (31%) | catalogued as COSV59019092; called by muse, mutect2, varscan2
- TTN | c.14856G>A p.L4952= (on ENST00000591111; = p.L4025= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 56/221 reads (25%) | catalogued as rs1291505269, COSV60418398; ClinVar: likely benign; called by muse, mutect2, varscan2
- TWNK | c.15C>T p.L5= | Silent (SNP) | VAF 32/93 reads (34%) | catalogued as rs1484939753, COSV52972993; called by muse, mutect2, varscan2
- UBQLNL | c.798G>A p.G266= | Silent (SNP) | VAF 24/70 reads (34%) | catalogued as COSV66494879; called by muse, mutect2, varscan2
- UGT3A1 | c.456C>T p.F152= | Silent (SNP) | VAF 21/64 reads (33%) | catalogued as COSV57103242; called by muse, mutect2, varscan2
- UQCC2 | c.114C>T p.A38= | Silent (SNP) | VAF 9/126 reads (7%) | catalogued as rs1397491288, COSV65269173; called by muse, mutect2
- WDR77 | c.285A>T p.L95= | Silent (SNP) | VAF 25/47 reads (53%) | catalogued as COSV52386428; called by muse, mutect2, varscan2
- ZBTB16 | c.1473C>T p.F491= | Silent (SNP) | VAF 18/45 reads (40%) | catalogued as COSV60088785; called by muse, mutect2, varscan2
- ZMYM3 | c.2910G>T p.L970= | Silent (SNP) | VAF 5/17 reads (29%) | catalogued as COSV58741399; called by muse, mutect2, varscan2
- ZNF512B | c.2199C>T p.N733= | Silent (SNP) | VAF 38/293 reads (13%) | catalogued as rs939271387, COSV53880310; called by muse, mutect2, varscan2
- ZNF646 | c.588C>T p.A196= | Silent (SNP) | VAF 5/49 reads (10%) | catalogued as COSV56220174; called by muse, mutect2
- DLGAP1 | c.1592-14809A>T | Intron (SNP) | VAF 3/25 reads (12%) | catalogued as COSV100232290; called by muse, mutect2
- LDB3 | c.896+6716T>A | Intron (SNP) | VAF 56/174 reads (32%) | catalogued as COSV99555520; called by muse, mutect2, varscan2
- LEKR1 | c.*1258A>G | 3'UTR (SNP) | VAF 23/83 reads (28%) | catalogued as COSV62965530; called by muse, mutect2, varscan2
- LIM2 | c.175+86G>A | Intron (SNP) | VAF 10/51 reads (20%) | catalogued as COSV55740551, COSV55742764; called by muse, mutect2
- LINC00174 | n.3297G>A | RNA (SNP) | VAF 4/12 reads (33%) | called by muse, mutect2
- MORF4 | n.396C>T | RNA (SNP) | VAF 19/89 reads (21%) | catalogued as rs1487987113; called by muse, mutect2, varscan2
- PRR22 | c.193+145C>T | Intron (SNP) | VAF 77/254 reads (30%) | catalogued as COSV100288318; called by muse, mutect2, varscan2
- RNPS1 | chr16:2271823 C>T | 5'Flank (SNP) | VAF 11/28 reads (39%) | catalogued as rs769476653; called by muse, mutect2, varscan2
- SERPINA13P | n.962G>A | RNA (SNP) | VAF 27/45 reads (60%) | catalogued as rs751567044; called by muse, mutect2, varscan2
- SLC22A17 | n.1297C>T | RNA (SNP) | VAF 30/109 reads (28%) | catalogued as rs928690935, COSV99248919; called by muse, mutect2, varscan2
- SLC22A17 | n.1296C>T | RNA (SNP) | VAF 30/110 reads (27%) | catalogued as COSV52837604, COSV52837665; called by muse, mutect2, varscan2
- TBC1D29P | n.2816C>T | RNA (SNP) | VAF 13/31 reads (42%) | catalogued as COSV70434335; called by muse, mutect2, varscan2
- TTN | c.10360+1882C>T | Intron (SNP) | VAF 13/39 reads (33%) | catalogued as COSV59961971, COSV60030941, COSV60268983; called by muse, varscan2
